Somatic mutation profile of tumor specimen TCGA-D9-A1JW-06A (aliquot TCGA-D9-A1JW-06A-11D-A19A-08) from TCGA case TCGA-D9-A1JW, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS.
Specimen TCGA-D9-A1JW-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f6389aeb-e119-45bd-bde1-af295a2b0a78.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D9-A1JW-10A (Blood Derived Normal), aliquot TCGA-D9-A1JW-10A-01D-A19A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2ecd376e-39ce-4de6-9abe-f20c7f0b9410

The open-access MAF lists 1,085 somatic variants for this specimen: 697 protein-altering or splice-affecting, 352 silent, 36 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 629, Silent 352, Nonsense Mutation 38, Splice Site 16, Intron 15, RNA 11, Splice Region 7, Frame Shift Del 4, 5'UTR 4, 5'Flank 3, Frame Shift Ins 2, 3'UTR 2.

Variants (750 of 1,085; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1862A>C p.N621T (on ENST00000288602 / NM_001374244.1; = p.N581T on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.186); catalogued as rs121913370, COSV56058108, COSV56106422, COSV56110832; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- COL3A1 | c.728G>A p.G243E | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587779629, CM000319, CM1412433, COSV58584704; ClinVar: pathogenic; called by muse, mutect2, varscan2
- EZH2 | c.1922A>T p.Y641F (on ENST00000460911 / NM_001203247.2; = p.Y646F on NM_004456.5) | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs267601394, COSV57445929, COSV57446008, COSV57446054; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- A2ML1 | c.1438G>A p.D480N | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.864); catalogued as rs368024371; called by muse, mutect2, varscan2
- AADAC | c.938G>A p.G313E | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.378); catalogued as rs867256779, COSV51759814; called by muse, mutect2, varscan2
- AADACL2 | c.275G>A p.R92Q | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs375818817; called by muse, mutect2, varscan2
- AATF | c.1433C>T p.S478F | Missense Mutation (SNP) | VAF 41/101 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.221); catalogued as rs765796809; called by muse, mutect2, varscan2
- ABCA8 | c.3946G>A p.D1316N | Missense Mutation (SNP) | VAF 65/150 reads (43%) | SIFT tolerated (0.27); PolyPhen benign (0.013); catalogued as rs759988499, COSV52199458; called by muse, mutect2, varscan2
- ABCB1 | c.2087C>T p.S696F | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55947943; called by muse, mutect2, varscan2
- ABCC11 | c.1072G>A p.E358K | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV62323526; called by muse, mutect2, varscan2
- ABCC2 | c.1745C>T p.S582F | Missense Mutation (SNP) | VAF 25/119 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64986585; called by muse, mutect2, varscan2
- ABCC4 | c.2900C>T p.S967F | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.835); catalogued as COSV65313348; called by muse, mutect2, varscan2
- ABCD2 | c.623A>G p.Q208R | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV58052141; called by muse, mutect2, varscan2
- ABHD12B | c.580G>A p.D194N (on ENST00000337334 / NM_001206673.2; = p.D117N on NM_181533.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/141 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV61569575; called by muse, mutect2, varscan2
- ACAN | c.650G>A p.R217Q | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757637229, COSV61361731; called by muse, mutect2, varscan2
- ACP7 | c.722C>T p.S241F | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV58699524; called by muse, mutect2, varscan2
- ACRBP | c.1562G>A p.G521D | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs1313167653, COSV57524119; called by muse, mutect2, varscan2
- ACSL3 | c.2041C>T p.R681C | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.014); catalogued as rs776538313, COSV62481117; called by muse, mutect2, varscan2
- ACSM2B | c.232G>A p.E78K | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.423); catalogued as COSV61657800; called by muse, mutect2, varscan2
- ACTB | c.794C>G p.S265C | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.001); catalogued as COSV100079467, COSV59321901; called by muse, mutect2, varscan2
- ACTN3 | c.391G>A p.D131N | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV101557815; called by muse, mutect2, varscan2
- ACVR1C | c.542C>T p.S181F | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54646656; called by muse, mutect2, varscan2
- ADAM20 | c.133C>T p.P45S | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56455164; called by muse, mutect2, varscan2
- ADAMTS13 | c.1437G>A p.G479= | Splice Region (SNP) | VAF 8/52 reads (15%) | catalogued as rs372953477, COSV63021506; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADAMTS20 | c.5257G>A p.E1753K | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs867354506, COSV67132676; called by muse, mutect2, varscan2
- ADCY10 | c.4742G>A p.W1581* | Nonsense Mutation (SNP) | VAF 39/89 reads (44%) | catalogued as COSV63241182; called by muse, mutect2, varscan2
- ADCY10 | c.1631C>T p.S544L | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.006); catalogued as COSV100897043, COSV63241188; called by muse, mutect2
- ADCY8 | c.1165G>A p.D389N | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.816); catalogued as rs983062571, COSV53910492; called by muse, mutect2, varscan2
- ADCY9 | c.812C>T p.S271L | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs757209625, COSV53576111; called by muse, mutect2, varscan2
- ADD2 | c.7G>A p.E3K | Missense Mutation (SNP) | VAF 29/99 reads (29%) | SIFT tolerated (0.46); PolyPhen benign (0.083); catalogued as rs200519011, COSV52457097; called by muse, mutect2, varscan2
- ADGRA3 | c.596A>G p.H199R | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.065); catalogued as rs951469992, COSV51563697; called by muse, mutect2, varscan2
- ADGRD1 | c.2522C>T p.S841L | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.182); catalogued as rs765449848, COSV55447120; called by muse, mutect2, varscan2
- ADGRG3 | c.1225C>T p.R409C | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.825); catalogued as rs111888711, COSV100342404; called by muse, mutect2, varscan2
- ADGRG7 | c.356G>A p.R119Q | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.963); catalogued as rs143646459; called by muse, mutect2, varscan2
- ADGRV1 | c.10979C>T p.S3660L | Missense Mutation (SNP) | VAF 49/118 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.158); catalogued as COSV101315748, COSV67986508; called by muse, mutect2, varscan2
- ADGRV1 | c.12691G>A p.E4231K | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.941); catalogued as COSV67993719, COSV67994462; called by muse, mutect2, varscan2
- ADH1C | c.271A>T p.I91F | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as COSV72463491; called by muse, mutect2, varscan2
- AGTPBP1 | c.2357C>T p.S786L (on ENST00000357081 / NM_001330701.2; = p.S746L on NM_015239.2) | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs1301788639, COSV61270146; called by mutect2, varscan2
- AHR | c.2292T>G p.C764W | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.867); catalogued as COSV54123948; called by muse, mutect2, varscan2
- AKAP9 | c.3892C>T p.P1298S | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT tolerated (0.95); PolyPhen benign (0.001); catalogued as COSV100662082; called by muse, mutect2, varscan2
- AKAP9 | c.3893C>T p.P1298L | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV100662084; called by muse, mutect2, varscan2
- AKAP9 | c.5935C>T p.R1979C (on ENST00000359028; = p.R1947C on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV62337737; called by muse, mutect2, varscan2
- AKNA | c.3516T>C p.S1172= | Splice Region (SNP) | VAF 9/29 reads (31%) | catalogued as COSV56337525; called by muse, mutect2, varscan2
- AKR1D1 | c.836G>A p.R279K | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.117); catalogued as rs765314823, COSV54337827; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AKR1E2 | c.575C>T p.T192I | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.14); catalogued as COSV53630639; called by muse, mutect2, varscan2
- AL441992.2 | c.547C>T p.P183S | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.5); catalogued as COSV56914195; called by muse, mutect2, varscan2
- ALDH1A2 | c.892G>T p.D298Y | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51082841; called by muse, mutect2, varscan2
- ALMS1 | c.7157C>A p.S2386Y | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.139); catalogued as COSV52511392; called by muse, mutect2, varscan2
- ALPP | c.1220G>A p.R407K | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT tolerated (0.85); PolyPhen benign (0.003); catalogued as COSV67396500; called by muse, varscan2
- AMPD1 | c.328C>T p.Q110* | Nonsense Mutation (SNP) | VAF 15/66 reads (23%) | catalogued as COSV62416515; called by muse, mutect2, varscan2
- ANK3 | c.12647G>A p.R4216Q (on ENST00000280772 / NM_001320874.2; = p.R840Q on NM_001149.3) | Missense Mutation (SNP) | VAF 27/104 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.753); catalogued as rs779784258, COSV55061029; called by muse, mutect2, varscan2
- ANO2 | c.2893C>A p.P965T (on ENST00000356134 / NM_001278597.3; = p.P969T on NM_001278596.3) | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.46); PolyPhen benign (0.013); catalogued as COSV59025671; called by muse, mutect2, varscan2
- APOB | c.10899G>A p.W3633* | Nonsense Mutation (SNP) | VAF 81/257 reads (32%) | catalogued as COSV51938071; called by muse, mutect2, varscan2
- APOB | c.8977G>A p.D2993N | Missense Mutation (SNP) | VAF 80/271 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.106); catalogued as rs1046539639, COSV51938081, COSV51941541; called by muse, mutect2, varscan2
- APOBEC3D | c.277C>T p.P93S | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT tolerated (0.5); PolyPhen benign (0.158); catalogued as COSV53326886; called by muse, mutect2, varscan2
- ARAP2 | c.1415C>T p.P472L | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58287486; called by muse, mutect2, varscan2
- ARFGEF1 | c.2668C>A p.L890I | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT tolerated (0.27); PolyPhen benign (0.101); catalogued as COSV51609622; called by muse, mutect2, varscan2
- ARFIP1 | c.524T>C p.I175T (on ENST00000353617 / NM_001287432.1; = p.I143T on NM_014447.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.119); catalogued as COSV61884800; called by muse, mutect2, varscan2
- ARHGAP39 | c.911C>T p.P304L | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1021189843, COSV52770991; called by muse, mutect2, varscan2
- ARHGEF10L | c.3133G>A p.E1045K | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.916); catalogued as COSV51433729; called by muse, mutect2, varscan2
- ARPP21 | c.2177A>T p.Y726F | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as COSV51799204; called by muse, mutect2, varscan2
- ATF2 | c.1088G>A p.R363K | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV51369906; called by muse, mutect2, varscan2
- ATP12A | c.353T>C p.L118P | Missense Mutation (SNP) | VAF 20/470 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV54517362; called by muse, mutect2
- ATP13A4 | c.1775G>A p.G592E | Missense Mutation (SNP) | VAF 37/115 reads (32%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.991); catalogued as rs1224524332, COSV55070096, COSV55070206; called by muse, mutect2, varscan2
- ATP13A4 | c.800G>A p.G267E | Missense Mutation (SNP) | VAF 30/132 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as rs1259918951, COSV55070104; called by muse, mutect2, varscan2
- ATP1A3 | c.356G>A p.G119D (on ENST00000545399 / NM_001256214.2; = p.G106D on NM_152296.5) | Missense Mutation (SNP) | VAF 24/145 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.037); catalogued as COSV57488095; called by muse, mutect2, varscan2
- ATP6V0A4 | c.1477A>T p.N493Y | Missense Mutation (SNP) | VAF 49/109 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV59476470; called by muse, mutect2, varscan2
- ATP6V1H | c.1268G>A p.R423Q | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs776565028, COSV62217609; called by muse, mutect2, varscan2
- ATP7A | c.4372A>G p.N1458D | Missense Mutation (SNP) | VAF 87/143 reads (61%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.64); catalogued as COSV58447213; called by muse, mutect2, varscan2
- ATP7B | c.3243G>A p.E1081= | Splice Region (SNP) | VAF 13/52 reads (25%) | catalogued as rs768229037, COSV99666168; called by muse, mutect2, varscan2
- AXDND1 | c.2587G>A p.E863K | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as COSV62639687; called by muse, mutect2, varscan2
- B3GALT1 | c.928G>A p.E310K | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.981); catalogued as COSV59908802; called by muse, mutect2, varscan2
- B3GNTL1 | c.667G>A p.D223N | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT tolerated (0.19); PolyPhen benign (0.029); catalogued as COSV57949729; called by muse, mutect2, varscan2
- BCL3 | c.346C>T p.P116S | Missense Mutation (SNP) | VAF 270/990 reads (27%) | SIFT tolerated (0.85); PolyPhen benign (0.003); catalogued as COSV51234289; called by muse, mutect2, varscan2
- BCL9 | c.940G>A p.V314M | Missense Mutation (SNP) | VAF 20/135 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.099); catalogued as COSV52344948; called by muse, mutect2, varscan2
- BCO2 | c.1327G>A p.G443R | Missense Mutation (SNP) | VAF 44/147 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.119); catalogued as COSV63063599; called by muse, mutect2, varscan2
- BICRAL | c.2789C>T p.A930V | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as rs564201366, COSV58406004; called by muse, mutect2, varscan2
- BPIFB4 | c.370C>T p.R124C | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.353); catalogued as rs140887073; called by muse, mutect2, varscan2
- BRINP1 | c.1741G>T p.E581* | Nonsense Mutation (SNP) | VAF 28/105 reads (27%) | catalogued as COSV56301734, COSV99774824; called by muse, mutect2, varscan2
- BTBD9 | c.1712C>T p.S571L | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs574266845, COSV58427240; called by muse, mutect2, varscan2
- BTNL3 | c.1021C>T p.H341Y | Missense Mutation (SNP) | VAF 38/170 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as rs974919422, COSV61565015; called by muse, mutect2, varscan2
- C10orf71 | c.538C>T p.P180S | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); catalogued as COSV60508485; called by muse, mutect2, varscan2
- C10orf71 | c.1768A>C p.T590P | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.885); catalogued as COSV60508503; called by muse, mutect2, varscan2
- C16orf70 | c.481C>T p.Q161* | Nonsense Mutation (SNP) | VAF 31/113 reads (27%) | catalogued as COSV54627535; called by muse, mutect2, varscan2
- C1orf210 | c.56C>T p.A19V | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.107); catalogued as COSV70682501; called by muse, mutect2, varscan2
- C20orf194 | c.3008C>T p.P1003L | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as COSV52696794, COSV99330828; called by muse, mutect2, varscan2
- C2orf16 | c.4505A>G p.N1502S | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.135); catalogued as COSV62676105; called by muse, mutect2, varscan2
- C4orf17 | c.190G>A p.G64R | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.682); catalogued as COSV58512630; called by muse, mutect2, varscan2
- C6 | c.866G>A p.R289K | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54707573; called by muse, mutect2, varscan2
- CACNA1B | c.5199G>A p.W1733* | Nonsense Mutation (SNP) | VAF 11/63 reads (17%) | catalogued as rs757905664, CM142863, COSV53115801, COSV53128540; called by muse, mutect2, varscan2
- CACNA1C | c.6149C>T p.S2050F (on ENST00000399634 / NM_001167625.1; = p.S1979F on NM_000719.7) | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.986); catalogued as COSV59725459; called by muse, varscan2
- CACNA1E | c.6512C>T p.S2171F (on ENST00000367573 / NM_001205293.3; = p.S2128F on NM_000721.4) | Missense Mutation (SNP) | VAF 30/149 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV62384483; called by muse, mutect2, varscan2
- CACNA1F | c.5270C>T p.S1757F | Missense Mutation (SNP) | VAF 20/28 reads (71%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as COSV59904861; called by muse, mutect2, varscan2
- CACNA2D2 | c.797G>A p.R266Q | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.444); catalogued as rs1288650707, COSV56564197; called by muse, mutect2
- CAMSAP3 | c.456G>A p.W152* | Nonsense Mutation (SNP) | VAF 58/124 reads (47%) | catalogued as COSV50336584; called by muse, mutect2, varscan2
- CARD9 | c.538G>A p.E180K | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.024); catalogued as COSV53733860; called by muse, mutect2, varscan2
- CBL | c.1250C>A p.P417H | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50629608, COSV50630632, COSV50639447; called by muse, mutect2, varscan2
- CBLB | c.2716C>T p.P906S | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.996); catalogued as COSV51427090; called by muse, mutect2, varscan2
- CCDC149 | c.529G>C p.E177Q | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100164932, COSV60879412; called by muse, mutect2, varscan2
- CCDC158 | c.154C>T p.P52S | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.011); catalogued as COSV66356176; called by muse, mutect2, varscan2
- CCDC27 | c.58G>A p.E20K | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.098); catalogued as COSV53900697; called by muse, mutect2, varscan2
- CCDC38 | c.1457G>A p.R486K | Missense Mutation (SNP) | VAF 47/200 reads (24%) | SIFT tolerated (0.73); PolyPhen benign (0.007); catalogued as COSV60183292; called by muse, mutect2, varscan2
- CCDC77 | c.523C>T p.Q175* | Nonsense Mutation (SNP) | VAF 30/115 reads (26%) | catalogued as COSV53473279; called by muse, mutect2, varscan2
- CCDC88B | c.3551G>A p.G1184D | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs752706848, COSV57266429, COSV57267073; called by muse, mutect2
- CCDC88C | c.3439G>A p.E1147K | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66238674; called by muse, mutect2, varscan2
- CCKAR | c.1058C>T p.S353F | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV55160299; called by muse, mutect2, varscan2
- CCT8L2 | c.773C>T p.T258M | Missense Mutation (SNP) | VAF 23/105 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as rs147789853, CM142324; called by muse, mutect2, varscan2
- CD109 | c.2491C>T p.P831S | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.027); catalogued as COSV54650303; called by muse, mutect2, varscan2
- CD163 | c.3251C>T p.S1084F | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT tolerated (0.78); PolyPhen benign (0.005); catalogued as COSV63133142; called by muse, mutect2, varscan2
- CD163 | c.1457C>T p.P486L | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as rs749287010, COSV100775829, COSV63133155; called by muse, mutect2, varscan2
- CD36 | c.245A>G p.N82S | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.27); PolyPhen benign (0.034); catalogued as COSV59213986; called by muse, mutect2, varscan2
- CD84 | c.590A>G p.N197S | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60868716; called by muse, mutect2, varscan2
- CDC20B | c.1222G>A p.D408N | Missense Mutation (SNP) | VAF 28/140 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs774926432, COSV57053151; called by muse, mutect2, varscan2
- CDC5L | c.2291C>T p.P764L | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV65176189; called by muse, mutect2
- CDH18 | c.2353G>A p.E785K | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.038); catalogued as rs149640304, COSV56926831; called by muse, mutect2, varscan2
- CDH20 | c.2244T>A p.Y748* | Nonsense Mutation (SNP) | VAF 9/39 reads (23%) | catalogued as COSV53010899; called by muse, mutect2, varscan2
- CDH9 | c.1349C>T p.S450L | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV50295740; called by muse, mutect2, varscan2
- CDX4 | c.682G>A p.E228K | Missense Mutation (SNP) | VAF 8/9 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65171688; called by muse, mutect2, varscan2
- CEP104 | c.1990A>T p.I664F | Missense Mutation (SNP) | VAF 51/186 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.308); catalogued as COSV65517719; called by muse, mutect2, varscan2
- CEP126 | c.539C>T p.S180L | Missense Mutation (SNP) | VAF 80/273 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.315); catalogued as COSV54825845; called by muse, mutect2, varscan2
- CEP44 | c.158A>T p.Y53F | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.021); catalogued as COSV56659523; called by muse, mutect2, varscan2
- CEP55 | c.749T>C p.V250A | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.85); PolyPhen benign (0.009); catalogued as COSV65185194; called by muse, mutect2, varscan2
- CERCAM | c.1331+2T>C p.X444_splice | Splice Site (SNP) | VAF 13/51 reads (25%) | catalogued as COSV65711136; called by muse, mutect2, varscan2
- CFAP47 | c.2786G>A p.G929E | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.943); catalogued as COSV52885482; called by muse, mutect2, varscan2
- CFAP69 | c.493G>T p.D165Y | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); catalogued as COSV60186231; called by muse, mutect2, varscan2
- CFHR5 | c.263C>T p.S88F | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV56818401; called by muse, mutect2, varscan2
- CHAD | c.772A>T p.K258* | Nonsense Mutation (SNP) | VAF 45/90 reads (50%) | catalogued as COSV51972782; called by muse, mutect2, varscan2
- CHD1L | c.194A>T p.N65I | Missense Mutation (SNP) | VAF 46/107 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV63614187; called by muse, mutect2, varscan2
- CHD5 | c.1657C>T p.P553S | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV52415888; called by muse, mutect2, varscan2
- CIAO1 | c.589G>C p.V197L | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV51498036; called by muse, mutect2, varscan2
- CIC | c.1485T>A p.F495L | Missense Mutation (SNP) | VAF 37/126 reads (29%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.827); catalogued as COSV50582399; called by muse, mutect2, varscan2
- CILP2 | c.3041C>T p.P1014L | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52275661; called by muse, mutect2, varscan2
- CLTRN | c.567G>A p.M189I | Missense Mutation (SNP) | VAF 11/17 reads (65%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV66711964; called by muse, mutect2, varscan2
- CLVS2 | c.871G>A p.E291K | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV51559280; called by muse, mutect2, varscan2
- CMKLR1 | c.103G>A p.E35K (on ENST00000312143 / NM_001142344.2; = p.E33K on NM_004072.3) | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.24); PolyPhen benign (0.014); catalogued as COSV56438748; called by muse, mutect2, varscan2
- CNTN3 | c.2174C>T p.P725L | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.864); catalogued as COSV55173197; called by muse, mutect2
- CNTN4 | c.2826G>A p.W942* | Nonsense Mutation (SNP) | VAF 15/62 reads (24%) | catalogued as COSV61874078; called by muse, mutect2, varscan2
- CNTNAP2 | c.2168C>T p.P723L | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV62189388; called by muse, mutect2, varscan2
- COL11A1 | c.5402C>T p.P1801L | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.419); catalogued as rs1247463879, COSV62185081; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL16A1 | c.3869C>T p.P1290L | Missense Mutation (SNP) | VAF 46/132 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs769525228, COSV54702062; called by muse, mutect2, varscan2
- COL16A1 | c.1303G>A p.G435R | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54707025; called by muse, mutect2, varscan2
- COL4A1 | c.989C>T p.P330L | Missense Mutation (SNP) | VAF 42/156 reads (27%) | SIFT tolerated (0.66); PolyPhen benign (0.005); catalogued as rs776465170, COSV65426784; called by muse, mutect2, varscan2
- COL4A3 | c.1823G>A p.G608E | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV67415922; called by muse, mutect2, varscan2
- COL4A4 | c.4058G>A p.R1353K | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.098); catalogued as rs747708741, COSV61632793; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL5A1 | c.607G>A p.G203S | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.568); catalogued as COSV65669659; called by muse, mutect2, varscan2
- COQ6 | c.1040C>T p.P347L | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53178921; called by muse, mutect2, varscan2
- CPLANE1 | c.9454C>T p.P3152S | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as COSV57061748; called by muse, mutect2, varscan2
- CPM | c.896A>C p.N299T | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.058); catalogued as COSV58033653; called by muse, mutect2, varscan2
- CR1 | c.3193C>T p.P1065S | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT tolerated (0.43); PolyPhen benign (0.028); catalogued as COSV65455623; called by muse, mutect2, varscan2
- CRB1 | c.1115C>T p.S372F | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.83); catalogued as rs1244838953, COSV66342014; called by muse, mutect2, varscan2
- CSMD3 | c.5048C>T p.S1683F (on ENST00000297405 / NM_001363185.1; = p.S1579F on NM_052900.3) | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); catalogued as COSV52119423, COSV99828086; called by muse, mutect2, varscan2
- CST6 | c.400C>T p.P134S | Missense Mutation (SNP) | VAF 33/140 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV56411073; called by muse, mutect2, varscan2
- CTPS1 | c.1171C>A p.Q391K | Missense Mutation (SNP) | VAF 29/120 reads (24%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as COSV101009295; called by muse, mutect2, varscan2
- CUX2 | c.2476C>T p.R826C | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1300303057, COSV55634535; called by muse, mutect2
- CXCL8 | c.98G>A p.R33K | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV56641054, COSV56641529; called by muse, mutect2, varscan2
- CYP17A1 | c.250G>A p.E84K | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV64004956; called by muse, mutect2, varscan2
- CYP2C8 | c.502T>A p.F168I | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.08); catalogued as COSV64877408; called by muse, mutect2, varscan2
- CYP3A43 | c.604C>T p.P202S | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.365); catalogued as rs200371261; called by muse, mutect2, varscan2
- CYP4A22 | c.1048G>A p.E350K | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53740651; called by muse, mutect2, varscan2
- CYP4B1 | c.32C>T p.S11F | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV54723954; called by muse, mutect2, varscan2
- DAB1 | c.401G>A p.G134E | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV59728759; called by muse, mutect2, varscan2
- DAZL | c.719G>A p.G240E | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.311); catalogued as COSV51712526; called by muse, mutect2, varscan2
- DBF4B | c.1429C>T p.P477S | Missense Mutation (SNP) | VAF 45/120 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as rs770361509, COSV59261012; called by muse, mutect2, varscan2
- DBH | c.115G>A p.G39S | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.561); catalogued as COSV99707958; called by muse, mutect2, varscan2
- DBH | c.116G>A p.G39D | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as COSV99707959; called by muse, mutect2, varscan2
- DCAKD | c.196C>T p.R66C | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777222686, COSV60201883; called by muse, mutect2, varscan2
- DCC | c.2447C>T p.S816F | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.763); catalogued as COSV59106095; called by muse, mutect2, varscan2
- DCLK1 | c.178C>T p.R60C | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.151); catalogued as COSV55171740; called by muse, mutect2, varscan2
- DENND4A | c.1081C>T p.P361S | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.114); catalogued as COSV71265956; called by muse, mutect2, varscan2
- DENND5A | c.2782G>T p.E928* | Nonsense Mutation (SNP) | VAF 29/84 reads (35%) | catalogued as rs1554910771, COSV60234184; called by muse, mutect2, varscan2
- DEPDC1B | c.1082C>T p.S361F | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.625); catalogued as rs199607798, COSV54010456; called by muse, mutect2, varscan2
- DGAT2L6 | c.823G>A p.G275S | Missense Mutation (SNP) | VAF 13/20 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60717907; called by muse, mutect2, varscan2
- DGKI | c.1084C>T p.R362C | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs774701094, COSV55953123; called by mutect2, varscan2
- DHX36 | c.2486A>T p.K829M | Missense Mutation (SNP) | VAF 27/115 reads (23%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.771); catalogued as COSV57673457; called by muse, mutect2, varscan2
- DLGAP4 | c.260C>T p.P87L | Missense Mutation (SNP) | VAF 32/98 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59418513; called by muse, mutect2, varscan2
- DNAH1 | c.9064C>T p.Q3022* | Nonsense Mutation (SNP) | VAF 4/21 reads (19%) | catalogued as COSV70229729; called by muse, mutect2
- DNAH17 | c.12245G>A p.R4082H | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750864747, COSV99428096; called by muse, mutect2, varscan2
- DNAH5 | c.7940C>T p.P2647L | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs756865161, COSV54229441; called by muse, mutect2, varscan2
- DNAH5 | c.2944C>T p.R982C | Missense Mutation (SNP) | VAF 19/111 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.15); catalogued as rs143673459; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DOCK3 | c.5013G>A p.M1671I | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs773161232, COSV56525336; called by muse, mutect2, varscan2
- DPYD | c.1991C>T p.A664V | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); catalogued as rs749982106, COSV64599335; called by muse, mutect2, varscan2
- DSC1 | c.2413G>A p.G805R | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1284822490, COSV57146365; called by muse, mutect2, varscan2
- DSCAM | c.4750G>A p.E1584K | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated (0.4); PolyPhen benign (0.028); catalogued as rs758792903, COSV68021636; called by muse, mutect2, varscan2
- DSPP | c.896C>T p.S299L | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.895); catalogued as COSV56808990; called by muse, mutect2, varscan2
- DTNBP1 | c.416G>A p.C139Y | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs1356149547, COSV59040586; called by muse, varscan2
- DUSP12 | c.844G>A p.G282R | Missense Mutation (SNP) | VAF 39/102 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100909688; called by muse, mutect2, varscan2
- DUSP22 | c.5G>A p.G2E | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as COSV60527529; called by muse, mutect2
- DYRK3 | c.829A>T p.S277C | Missense Mutation (SNP) | VAF 23/119 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.125); catalogued as COSV65606452; called by muse, mutect2, varscan2
- DYRK4 | c.700G>A p.E234K | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV50539978; called by muse, mutect2, varscan2
- E4F1 | c.1384C>T p.P462S | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.459); catalogued as COSV57039328; called by muse, mutect2, varscan2
- EFCAB3 | c.730C>T p.P244S | Missense Mutation (SNP) | VAF 43/81 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59502415; called by muse, mutect2, varscan2
- EFCAB7 | c.295G>C p.E99Q | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV64314649; called by muse, mutect2, varscan2
- EHBP1 | c.731C>T p.S244F | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.564); catalogued as COSV50416086; called by muse, mutect2, varscan2
- ELAC2 | c.2023C>T p.R675W | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.606); catalogued as rs1157458251, COSV52395052; called by muse, mutect2, varscan2
- ELOA2 | c.553G>A p.E185K | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.046); catalogued as COSV55300382; called by muse, mutect2, varscan2
- ENAM | c.812G>A p.G271E | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); catalogued as rs745482726, COSV68536094; called by muse, mutect2, varscan2
- ERICH3 | c.3758G>A p.G1253E | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as COSV58608382; called by muse, mutect2, varscan2
- ERICH3 | c.1121C>T p.S374F | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV58608388; called by muse, mutect2, varscan2
- EVC2 | c.926C>T p.S309F | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747880765, COSV60390255; called by muse, mutect2, varscan2
- EVI5L | c.976G>A p.G326R | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV54486041; called by muse, mutect2
- EXD2 | c.877C>T p.R293* (on ENST00000312994 / NM_001193362.1; = p.R168* on NM_018199.3) | Nonsense Mutation (SNP) | VAF 18/67 reads (27%) | catalogued as rs770383229, COSV57279774; called by muse, mutect2, varscan2
- EXOC3L1 | c.523G>A p.D175N | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as COSV52046629; called by muse, mutect2, varscan2
- EXOC3L4 | c.1648A>T p.K550* | Nonsense Mutation (SNP) | VAF 11/52 reads (21%) | catalogued as COSV66295592; called by muse, mutect2, varscan2
- EYA1 | c.1605A>T p.E535D | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.911); catalogued as COSV58164308; called by muse, mutect2, varscan2
- FAAH2 | c.340G>A p.E114K | Missense Mutation (SNP) | VAF 3/8 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.068); catalogued as COSV66508095; called by muse, mutect2
- FABP9 | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.38); PolyPhen benign (0.115); catalogued as COSV66911599; called by muse, mutect2, varscan2
- FAIM2 | c.133G>A p.E45K | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.67); PolyPhen benign (0.129); catalogued as COSV57737799, COSV57739575; called by muse, mutect2, varscan2
- FAM135B | c.1699G>A p.E567K | Missense Mutation (SNP) | VAF 23/118 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.439); catalogued as rs772418841, COSV52715727; called by muse, mutect2, varscan2
- FAM171A1 | c.566G>A p.G189E | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV65316670; called by muse, mutect2, varscan2
- FAM47A | c.584C>T p.P195L | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT tolerated (0.22); PolyPhen benign (0.057); catalogued as rs1301512208, COSV100649985, COSV60494608; called by muse, mutect2, varscan2
- FAM71B | c.1316C>T p.P439L | Missense Mutation (SNP) | VAF 476/992 reads (48%) | SIFT tolerated (0.36); PolyPhen benign (0.024); catalogued as rs1055104938, COSV57228630, COSV57228938; called by muse, mutect2, varscan2
- FAM71B | c.733G>A p.A245T | Missense Mutation (SNP) | VAF 191/399 reads (48%) | SIFT tolerated (0.78); PolyPhen benign (0.001); catalogued as COSV57229359; called by muse, mutect2, varscan2
- FAM83E | c.1126G>A p.D376N | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV52376373; called by muse, mutect2, varscan2
- FASN | c.4646C>T p.S1549F | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60755725; called by mutect2, varscan2
- FAT2 | c.1726G>A p.D576N | Missense Mutation (SNP) | VAF 88/176 reads (50%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); catalogued as COSV55820876; called by muse, mutect2, varscan2
- FAT2 | c.982G>A p.G328R | Missense Mutation (SNP) | VAF 93/238 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV55820883; called by muse, mutect2, varscan2
- FAT4 | c.1415C>T p.P472L | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1205861022, COSV67888238; called by muse, mutect2, varscan2
- FBLN5 | c.1304C>T p.S435F | Missense Mutation (SNP) | VAF 29/124 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV50904305; called by muse, mutect2, varscan2
- FBN3 | c.2146G>A p.G716S | Missense Mutation (SNP) | VAF 25/48 reads (52%) | SIFT tolerated (0.08); PolyPhen benign (0.341); catalogued as rs868545952, COSV54462552; called by muse, mutect2, varscan2
- FBXW7 | c.1548T>G p.S516R (on ENST00000281708 / NM_001349798.2; = p.S436R on NM_018315.5) | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55921295; called by muse, mutect2, varscan2
- FCRL1 | c.868G>A p.V290M | Missense Mutation (SNP) | VAF 38/93 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV63825553; called by muse, mutect2, varscan2
- FDPS | c.72G>C p.E24D | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as COSV63114635; called by muse, mutect2
- FER1L6 | c.934G>A p.E312K | Missense Mutation (SNP) | VAF 51/130 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67548489; called by muse, mutect2, varscan2
- FER1L6 | c.5405C>T p.S1802F | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67549439; called by muse, mutect2, varscan2
- FH | c.1489T>C p.F497L | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.432); catalogued as COSV63818276; called by muse, mutect2
- FILIP1 | c.3334C>T p.P1112S | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.386); catalogued as COSV52723327; called by muse, mutect2, varscan2
- FLG | c.11990G>A p.G3997E | Missense Mutation (SNP) | VAF 29/123 reads (24%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.455); catalogued as rs149094882; called by muse, mutect2, varscan2
- FLG2 | c.139-1G>A p.X47_splice | Splice Site (SNP) | VAF 4/37 reads (11%) | catalogued as COSV101165676, COSV66174868; called by muse, mutect2
- FLNC | c.2072C>T p.T691I | Missense Mutation (SNP) | VAF 58/251 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.119); catalogued as COSV57956871; called by muse, mutect2, varscan2
- FMO3 | c.688C>T p.P230S | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs868604370, COSV63007410; called by muse, mutect2, varscan2
- FNDC3B | c.2090C>T p.S697L | Missense Mutation (SNP) | VAF 26/121 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.009); catalogued as rs755249189, COSV61043413; called by muse, mutect2, varscan2
- FOXP1 | c.2002G>A p.E668K | Missense Mutation (SNP) | VAF 48/192 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as rs866381610, COSV59535539; called by muse, mutect2, varscan2
- FPGS | c.700G>A p.D234N | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.111); catalogued as COSV64675720; called by muse, mutect2, varscan2
- FRAS1 | c.9209G>A p.R3070K | Missense Mutation (SNP) | VAF 31/104 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.065); catalogued as COSV53615503, COSV53646389; called by muse, mutect2, varscan2
- FREM2 | c.2872G>A p.E958K | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV54839909; called by muse, mutect2, varscan2
- FREM2 | c.5293C>T p.R1765C | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.02); catalogued as rs770772406, COSV54826790; called by muse, mutect2, varscan2
- FRMPD4 | c.905C>T p.P302L | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.155); catalogued as COSV66215938; called by muse, mutect2, varscan2
- FSTL5 | c.2512G>A p.G838R | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV60181692; called by muse, mutect2, varscan2
- FYB2 | c.1391G>A p.G464E | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.13); catalogued as COSV58585677; called by muse, mutect2
- FYTTD1 | c.811C>T p.P271S | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54082603; called by muse, mutect2, varscan2
- GALNT17 | c.1033C>T p.P345S | Missense Mutation (SNP) | VAF 38/144 reads (26%) | SIFT tolerated (0.41); PolyPhen benign (0.022); catalogued as rs751577191, COSV61164917; called by muse, mutect2, varscan2
- GALNTL6 | c.145C>T p.P49S | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV72491261; called by muse, mutect2, varscan2
- GEM | c.451G>A p.D151N | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT tolerated (0.3); PolyPhen benign (0.377); catalogued as COSV52597599; called by muse, mutect2, varscan2
- GEN1 | c.637-1G>A p.X213_splice | Splice Site (SNP) | VAF 5/24 reads (21%) | catalogued as COSV100438205, COSV58056871; called by muse, mutect2, varscan2
- GFRA1 | c.1099A>T p.T367S | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated (0.35); PolyPhen benign (0.051); catalogued as COSV62606563; called by muse, mutect2, varscan2
- GFUS | c.775G>A p.V259M | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.526); catalogued as COSV55307159; called by muse, mutect2
- GGT7 | c.628C>T p.P210S | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60541038; called by muse, mutect2, varscan2
- GLYATL1 | c.299G>A p.R100K (on ENST00000317391 / NM_001354699.1; = p.R131K on NM_080661.4) | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1167312597, COSV55609135, COSV55609621; called by muse, mutect2, varscan2
- GML | c.371C>A p.P124H | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.758); catalogued as COSV55277472; called by muse, mutect2, varscan2
- GP9 | c.55G>A p.D19N | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0.432); catalogued as COSV56624226; called by muse, mutect2, varscan2
- GRB7 | c.1145G>A p.G382E | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58448323; called by muse, mutect2, varscan2
- GRIK1 | c.478G>A p.A160T | Missense Mutation (SNP) | VAF 38/106 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58719819; called by muse, mutect2, varscan2
- GTF3C2 | c.1459C>T p.P487S | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as COSV99272343; called by muse, mutect2, varscan2
- GTSE1 | c.1763C>T p.S588F | Missense Mutation (SNP) | VAF 31/124 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.111); catalogued as rs750967626, COSV71889163; called by muse, mutect2, varscan2
- GUCY2F | c.838C>T p.P280S | Missense Mutation (SNP) | VAF 36/76 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.145); catalogued as rs755278764, COSV54303203; called by muse, mutect2, varscan2
- HABP2 | c.394C>T p.P132S | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); catalogued as rs972928454, COSV63636917; called by muse, mutect2, varscan2
- HCN1 | c.1645C>T p.R549C | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs868454030, COSV57495992, COSV57527391; called by muse, mutect2, varscan2
- HCN1 | c.435G>A p.W145* | Nonsense Mutation (SNP) | VAF 7/16 reads (44%) | catalogued as COSV57506828, COSV57514204; called by muse, mutect2, varscan2
- HCN3 | c.1652A>G p.N551S | Missense Mutation (SNP) | VAF 80/160 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.039); catalogued as COSV61361390; called by muse, mutect2, varscan2
- HDGF | c.178C>T p.P60S | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0.087); catalogued as COSV61976463; called by muse, mutect2, varscan2
- HEATR5A | c.1468C>T p.R490C | Missense Mutation (SNP) | VAF 43/156 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as rs758539397, COSV66341578; called by muse, mutect2, varscan2
- HELLS | c.258G>A p.M86I | Missense Mutation (SNP) | VAF 25/109 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0.061); catalogued as COSV99491837; called by muse, mutect2, varscan2
- HELLS | c.259G>A p.E87K | Missense Mutation (SNP) | VAF 25/111 reads (23%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.886); catalogued as COSV99491840; called by muse, mutect2, varscan2
- HEPHL1 | c.1732G>A p.E578K | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV59891267; called by muse, mutect2, varscan2
- HERC1 | c.3361A>G p.I1121V | Missense Mutation (SNP) | VAF 30/96 reads (31%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs1374269595, COSV71248093; called by muse, mutect2, varscan2
- HFM1 | c.802C>T p.P268S | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.95); catalogued as rs199692136; called by muse, mutect2, varscan2
- HID1 | c.469G>A p.D157N | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.744); catalogued as COSV59351631; called by muse, mutect2
- HIPK3 | c.1216G>A p.D406N | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV57562906; called by muse, mutect2, varscan2
- HNF1A | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 80/305 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.109); catalogued as COSV57462851, COSV57468194; called by muse, mutect2, varscan2
- HNRNPCL1 | c.724G>A p.G242R | Missense Mutation (SNP) | VAF 35/156 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs537856884, COSV58611968; called by muse, mutect2, varscan2
- HNRNPCL1 | c.278G>A p.G93E | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV58609764; called by muse, mutect2, varscan2
- HNRNPM | c.928C>T p.P310S | Missense Mutation (SNP) | VAF 32/52 reads (62%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as COSV57692894; called by muse, mutect2, varscan2
- HRG | c.830C>T p.P277L | Missense Mutation (SNP) | VAF 22/105 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.033); catalogued as COSV51645985; called by muse, mutect2, varscan2
- HS3ST1 | c.773G>A p.R258Q | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.488); catalogued as rs1218413396, COSV50023865, COSV50026256, COSV99136641; called by muse, mutect2, varscan2
- HS3ST2 | c.793C>T p.P265S | Missense Mutation (SNP) | VAF 60/206 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV54462986; called by muse, mutect2, varscan2
- HSD17B2 | c.541C>T p.L181F | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); catalogued as COSV52276321; called by muse, mutect2, varscan2
- HSD17B3 | c.406C>T p.P136S | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.61); PolyPhen benign (0.438); catalogued as COSV64557170; called by muse, varscan2
- HTRA1 | c.712T>C p.Y238H | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.721); catalogued as COSV64564355; called by muse, mutect2, varscan2
- HYDIN | c.13492C>T p.P4498S | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.812); catalogued as COSV66639370; called by muse, mutect2, varscan2
- HYDIN | c.5965C>T p.Q1989* | Nonsense Mutation (SNP) | VAF 13/61 reads (21%) | catalogued as COSV59258787; called by muse, mutect2, varscan2
- HYDIN | c.68G>A p.G23E | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.13); catalogued as rs1253207693, COSV55482176; called by muse, mutect2, varscan2
- ICE2 | c.2867C>T p.S956F | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV55031752; called by muse, mutect2, varscan2
- IFNAR2 | c.464C>T p.P155L | Missense Mutation (SNP) | VAF 32/129 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV59746460; called by muse, mutect2, varscan2
- IGDCC4 | c.3572C>T p.A1191V | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.042); catalogued as COSV100732750; called by muse, mutect2, varscan2
- IGKV1-9 | c.119G>A p.R40K | Missense Mutation (SNP) | VAF 46/188 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as rs753574997; called by muse, mutect2, varscan2
- IGSF21 | c.412C>T p.L138F | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV52134723, COSV52139090; called by muse, mutect2, varscan2
- IKZF1 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.987); catalogued as COSV58786520; called by muse, mutect2, varscan2
- IKZF4 | c.1087C>T p.H363Y | Missense Mutation (SNP) | VAF 40/149 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.042); catalogued as COSV56268758; called by muse, varscan2
- IKZF4 | c.1228C>T p.P410S | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV56268779; called by muse, varscan2
- IL37 | c.409-1G>A p.X137_splice | Splice Site (SNP) | VAF 15/68 reads (22%) | catalogued as COSV54491390; called by muse, mutect2, varscan2
- IQCJ | c.472C>T p.L158F | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.025); catalogued as COSV101188142; called by muse, mutect2, varscan2
- ITGA9 | c.1988A>G p.N663S | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs987746540, COSV53243851; called by muse, mutect2, varscan2
- ITIH1 | c.1513G>A p.E505K | Missense Mutation (SNP) | VAF 42/149 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0.109); catalogued as rs777653995, COSV56252901; called by muse, mutect2, varscan2
- KALRN | c.6733G>A p.E2245K (on ENST00000360013 / NM_001024660.4; = p.E548K on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/111 reads (28%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.988); catalogued as COSV52257627; called by muse, varscan2
- KCNA3 | c.1189G>A p.E397K | Missense Mutation (SNP) | VAF 27/96 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63901746, COSV63902618; called by muse, mutect2, varscan2
- KCNA6 | c.724G>A p.E242K | Missense Mutation (SNP) | VAF 38/148 reads (26%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as rs866418364, COSV54974491; called by muse, mutect2, varscan2
- KCNC3 | c.2044C>T p.Q682* | Nonsense Mutation (SNP) | VAF 20/60 reads (33%) | catalogued as rs1407795965, COSV65387712; called by muse, mutect2, varscan2
- KCNH4 | c.641G>A p.G214E | Missense Mutation (SNP) | VAF 28/207 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV99236898; called by muse, mutect2, varscan2
- KCNH6 | c.2920C>T p.P974S | Missense Mutation (SNP) | VAF 28/167 reads (17%) | SIFT tolerated, low confidence (0.82); PolyPhen benign (0.113); catalogued as rs200206448; called by muse, mutect2, varscan2
- KCNJ10 | c.353C>T p.A118V | Missense Mutation (SNP) | VAF 26/132 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63633950; called by muse, mutect2, varscan2
- KCNMB3 | c.195G>A p.M65I | Missense Mutation (SNP) | VAF 35/118 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.492); catalogued as COSV58570658; called by muse, mutect2, varscan2
- KCNT2 | c.2036G>A p.G679E | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs267598261, COSV54073484; called by muse, mutect2, varscan2
- KDR | c.3299C>T p.S1100F | Missense Mutation (SNP) | VAF 29/106 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs868047715, COSV55764136; called by muse, mutect2, varscan2
- KHDRBS1 | c.901C>T p.P301S | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV56982217; called by muse, mutect2, varscan2
- KIAA1109 | c.319C>T p.R107W | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs781331445, COSV52675771; called by muse, mutect2, varscan2
- KIAA1614 | c.3151C>G p.L1051V | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100799742; called by muse, mutect2, varscan2
- KIAA2026 | c.3494C>A p.P1165Q | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.715); catalogued as COSV67355504; called by muse, mutect2, varscan2
- KIF15 | c.1546G>A p.E516K | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV58161234, COSV58163293; called by muse, mutect2, varscan2
- KIF15 | c.3943A>T p.M1315L | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV100392621; called by muse, mutect2, varscan2
- KIF19 | c.1259G>A p.G420E | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs1395344368, COSV63429591; called by muse, mutect2
- KIF1B | c.4964C>T p.S1655F (on ENST00000377086 / NM_001365952.1; = p.S1609F on NM_015074.3) | Missense Mutation (SNP) | VAF 71/330 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.395); catalogued as COSV55809622; called by muse, mutect2, varscan2
- KIF25 | c.563C>T p.P188L | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.326); catalogued as COSV63027538; called by muse, mutect2, varscan2
- KIF2B | c.301G>A p.A101T | Missense Mutation (SNP) | VAF 81/223 reads (36%) | SIFT tolerated (0.36); PolyPhen benign (0.006); catalogued as COSV99274892; called by muse, mutect2, varscan2
- KIR3DL2 | c.88T>C p.F30L | Missense Mutation (SNP) | VAF 58/211 reads (27%) | SIFT tolerated (1); PolyPhen possibly damaging (0.467); catalogued as COSV99551853; called by muse, mutect2, varscan2
- KLHL1 | c.1913G>A p.G638E | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64773568; called by muse, mutect2, varscan2
- KLHL13 | c.1112C>T p.S371L | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.011); catalogued as rs1314523330, COSV53245217; called by muse, mutect2, varscan2
- KLHL14 | c.952C>T p.R318C | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs371937062; called by muse, mutect2, varscan2
- KLHL7 | c.664C>T p.R222C (on ENST00000339077 / NM_001031710.3; = p.R174C on NM_018846.5) | Missense Mutation (SNP) | VAF 46/161 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs748221520, COSV59161409, COSV59161877; called by muse, mutect2, varscan2
- KLK11 | c.40G>A p.G14S | Missense Mutation (SNP) | VAF 51/188 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.001); catalogued as COSV51577380; called by muse, mutect2, varscan2
- KMT2D | c.3362A>C p.D1121A | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.378); catalogued as COSV56447171; called by muse, mutect2
- KRT32 | c.575G>A p.R192Q | Missense Mutation (SNP) | VAF 30/119 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs200664830, COSV56786831; called by muse, mutect2, varscan2
- KRT77 | c.1027G>A p.E343K | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); catalogued as COSV59239843; called by muse, mutect2, varscan2
- KRT77 | c.269G>A p.G90E | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as COSV59240017; called by muse, mutect2, varscan2
- KRTAP12-1 | c.98C>T p.S33F | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.601); catalogued as COSV59964883; called by muse, mutect2, varscan2
- KRTAP4-5 | c.44G>A p.C15Y | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.587); catalogued as COSV58352432; called by muse, mutect2, varscan2
- LAMA4 | c.2098G>A p.G700R (on ENST00000230538 / NM_001105206.3; = p.G693R on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/92 reads (39%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.771); catalogued as rs782527358, COSV57898139; called by muse, mutect2, varscan2
- LAMA5 | c.5275C>T p.R1759C | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.659); catalogued as rs369951035; called by muse, mutect2, varscan2
- LAMB4 | c.4680-1G>A p.X1560_splice | Splice Site (SNP) | VAF 18/55 reads (33%) | catalogued as COSV52720662; called by muse, mutect2, varscan2
- LILRA2 | c.266G>A p.W89* | Nonsense Mutation (SNP) | VAF 24/85 reads (28%) | catalogued as COSV52192360; called by muse, mutect2, varscan2
- LILRB1 | c.1640G>A p.R547K (on ENST00000427581; = p.R497K on NM_006669.6) | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.52); PolyPhen benign (0.075); catalogued as COSV100207040; called by muse, mutect2
- LIN54 | c.115C>T p.P39S | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.099); catalogued as COSV61201466; called by muse, mutect2, varscan2
- LLGL1 | c.598T>G p.S200A | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57498426; called by muse, mutect2, varscan2
- LMO3 | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.73); PolyPhen benign (0.114); catalogued as rs764774588, COSV53782882; called by muse, mutect2, varscan2
- LMO7 | c.1967G>A p.R656K (on ENST00000357063; = p.R386K on NM_015842.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58538277; called by muse, mutect2, varscan2
- LPAR1 | c.341G>A p.R114Q | Missense Mutation (SNP) | VAF 25/120 reads (21%) | SIFT tolerated (0.29); PolyPhen benign (0.046); catalogued as rs778252713, COSV100730761; called by muse, mutect2, varscan2
- LPIN3 | c.1969C>T p.H657Y | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV60036624; called by muse, mutect2, varscan2
- LRIG3 | c.1756C>T p.H586Y | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.941); catalogued as COSV57864886; called by muse, mutect2, varscan2
- LRIT3 | c.1108C>T p.Q370* | Nonsense Mutation (SNP) | VAF 52/182 reads (29%) | catalogued as COSV59985733; called by muse, mutect2, varscan2
- LRP1B | c.9222T>A p.C3074* | Nonsense Mutation (SNP) | VAF 9/40 reads (23%) | catalogued as COSV67194870; called by muse, mutect2, varscan2
- LRRC37A3 | c.3931C>T p.R1311C | Missense Mutation (SNP) | VAF 257/436 reads (59%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs752685034, COSV58535521; called by muse, mutect2, varscan2
- LRRC55 | c.536T>C p.L179P | Missense Mutation (SNP) | VAF 39/118 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.047); catalogued as COSV73006581; called by muse, mutect2, varscan2
- LRRC74A | c.307C>T p.R103W | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs377584165, COSV53609076; called by muse, mutect2, varscan2
- LRRIQ1 | c.2057G>A p.G686D | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV67831714; called by muse, mutect2, varscan2
- LRRIQ1 | c.3650G>A p.R1217Q | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs765567234, COSV67831721; called by muse, mutect2, varscan2
- LRWD1 | c.304C>T p.P102S | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.43); PolyPhen benign (0.236); catalogued as COSV52961107; called by muse, mutect2, varscan2
- LTBP2 | c.4907G>T p.C1636F | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56208958; called by muse, mutect2, varscan2
- LY96 | c.386G>T p.G129V | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53025605; called by muse, mutect2, varscan2
- MAGEA3 | c.200G>A p.G67E | Missense Mutation (SNP) | VAF 17/28 reads (61%) | SIFT tolerated (0.95); PolyPhen possibly damaging (0.647); catalogued as COSV100939012; called by muse, mutect2, varscan2
- MAGEC1 | c.659G>A p.R220K | Missense Mutation (SNP) | VAF 45/183 reads (25%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.001); catalogued as rs1191255686, COSV53567753, COSV53573844; called by muse, varscan2
- MAGEC1 | c.1210C>T p.P404S | Missense Mutation (SNP) | VAF 82/156 reads (53%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.058); catalogued as COSV99594673; called by muse, mutect2, varscan2
- MAGEC1 | c.1693C>T p.P565S | Missense Mutation (SNP) | VAF 122/239 reads (51%) | SIFT tolerated, low confidence (0.15); PolyPhen possibly damaging (0.775); catalogued as COSV53573855; called by muse, mutect2, varscan2
- MAGEE2 | c.1501G>A p.E501K | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV64897598; called by muse, mutect2, varscan2
- MAP9 | c.638C>T p.S213F | Missense Mutation (SNP) | VAF 29/101 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV60904923; called by muse, mutect2, varscan2
- MARK3 | c.2014C>T p.P672S (on ENST00000429436 / NM_001128918.3; = p.P648S on NM_002376.6) | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53510472, COSV53511037; called by muse, mutect2, varscan2
- MASP2 | c.1222+1G>A p.X408_splice | Splice Site (SNP) | VAF 6/41 reads (15%) | catalogued as COSV101280096; called by muse, mutect2, varscan2
- MBL2 | c.221G>A p.G74E | Missense Mutation (SNP) | VAF 26/117 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64758651; called by muse, mutect2, varscan2
- MCM3 | c.763C>T p.P255S (on ENST00000229854 / NM_001366374.2; = p.P245S on NM_002388.6 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 42/99 reads (42%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.956); catalogued as COSV57716677; called by muse, mutect2, varscan2
- MIGA2 | c.1264C>T p.R422* | Nonsense Mutation (SNP) | VAF 7/21 reads (33%) | catalogued as rs772417964, COSV52977154; called by muse, mutect2, varscan2
- MISP | c.1114G>A p.V372M | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated (0.16); PolyPhen benign (0.127); catalogued as rs763322011, COSV53120522; called by muse, mutect2
- MKI67 | c.6173G>A p.G2058E | Missense Mutation (SNP) | VAF 69/265 reads (26%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.972); catalogued as COSV100896304; called by muse, mutect2, varscan2
- MKI67 | c.6172G>A p.G2058R | Missense Mutation (SNP) | VAF 68/263 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.875); catalogued as COSV100896306; called by muse, mutect2, varscan2
- MKLN1 | c.166C>G p.Q56E | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.194); catalogued as COSV61761094; called by muse, mutect2, varscan2
- MKRN3 | c.158G>A p.R53K | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as COSV58810151; called by muse, mutect2, varscan2
- MOGS | c.754G>A p.D252N | Missense Mutation (SNP) | VAF 40/171 reads (23%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV52028395; called by muse, mutect2, varscan2
- MORC1 | c.2743G>A p.D915N | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs1173188517, COSV51719800, COSV51732735; called by muse, mutect2, varscan2
- MOXD1 | c.1306G>A p.G436R | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60945067; called by muse, mutect2, varscan2
- MRGPRX2 | c.89C>T p.T30I | Missense Mutation (SNP) | VAF 89/275 reads (32%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as rs760846706, COSV61674277; called by muse, mutect2, varscan2
- MSR1 | c.196C>T p.P66S | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.997); catalogued as COSV100028288, COSV50513878; called by muse, mutect2, varscan2
- MTR | c.2909T>G p.V970G | Missense Mutation (SNP) | VAF 8/109 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.567); catalogued as COSV63965113; called by muse, mutect2
- MUC16 | c.34708G>A p.E11570K | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.023); catalogued as rs1180015154, COSV67470444; called by muse, mutect2, varscan2
- MUC16 | c.25187C>T p.S8396F | Missense Mutation (SNP) | VAF 26/48 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.865); catalogued as COSV101198768; called by muse, mutect2, varscan2
- MUC16 | c.3734C>T p.S1245L | Missense Mutation (SNP) | VAF 203/404 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.071); catalogued as COSV67464105, COSV67470453; called by muse, mutect2, varscan2
- MUC5B | c.5560G>A p.G1854R | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71592371; called by muse, mutect2, varscan2
- MXRA5 | c.4612G>A p.E1538K | Missense Mutation (SNP) | VAF 32/53 reads (60%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV54237566; called by muse, mutect2, varscan2
- MYBPH | c.676G>A p.D226N | Missense Mutation (SNP) | VAF 25/46 reads (54%) | SIFT tolerated (0.12); PolyPhen benign (0.091); catalogued as rs1319674600, COSV55142713; called by muse, mutect2, varscan2
- MYH2 | c.382C>T p.P128S | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.774); catalogued as COSV55439638; called by muse, mutect2, varscan2
- MYH4 | c.5447T>G p.I1816S | Missense Mutation (SNP) | VAF 35/127 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.799); catalogued as COSV55119270; called by muse, mutect2, varscan2
- MYH7B | c.4919G>A p.R1640Q | Missense Mutation (SNP) | VAF 83/306 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.852); catalogued as rs200483933, COSV52680518; called by muse, mutect2, varscan2
- MYLK | c.1070G>A p.R357K | Missense Mutation (SNP) | VAF 44/170 reads (26%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV60611734; called by muse, mutect2, varscan2
- MYLK | c.665G>A p.G222E | Missense Mutation (SNP) | VAF 36/143 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV60611747; called by muse, mutect2, varscan2
- MYO1D | c.665A>C p.Q222P | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.894); catalogued as COSV59014435; called by muse, mutect2, varscan2
- MYO3A | c.1507G>A p.G503R | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV56333306; called by muse, mutect2, varscan2
- MYO5B | c.601C>T p.P201S | Missense Mutation (SNP) | VAF 24/99 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV53220340; called by muse, mutect2, varscan2
- MYO5C | c.353G>A p.G118E | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.823); catalogued as rs1263083335, COSV55907156; called by muse, mutect2, varscan2
- MYO7A | c.1978G>A p.G660R | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68684952; called by muse, mutect2, varscan2
- MYRIP | c.1628C>T p.S543F | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.77); catalogued as rs745676606, COSV56870613; called by muse, mutect2, varscan2
- NCAPH2 | c.719C>T p.S240F | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.5); catalogued as rs201371265, COSV53218782; called by muse, mutect2, varscan2
- NCOA2 | c.1151C>T p.P384L | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs748237390, COSV71763312; called by muse, mutect2, varscan2
- NCOA6 | c.5240C>T p.P1747L | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.039); catalogued as COSV62861826; called by muse, mutect2, varscan2
- NDST4 | c.1980T>A p.S660R | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.251); catalogued as COSV99995802; called by muse, varscan2
- NDST4 | c.1557T>A p.H519Q | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99995803; called by mutect2, varscan2
- NDUFAF2 | c.485G>A p.R162Q | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs374701660; ClinVar: likely benign; called by muse, mutect2, varscan2
- NDUFS1 | c.847G>A p.E283K | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51910228; called by muse, mutect2, varscan2
- NEBL | c.1634T>G p.I545S | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.074); catalogued as COSV65803346; called by muse, mutect2, varscan2
- NEDD9 | c.734C>T p.P245L | Missense Mutation (SNP) | VAF 36/94 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.034); catalogued as rs774818140, COSV65221569; called by muse, mutect2, varscan2
- NEXMIF | c.3328G>A p.E1110K | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.154); catalogued as COSV50021799; called by muse, mutect2, varscan2
- NFKBID | c.670C>T p.Q224* (on ENST00000396901; = p.Q376* on NM_032721.3 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 35/102 reads (34%) | catalogued as COSV61728971; called by muse, mutect2, varscan2
- NINL | c.266C>T p.S89F | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.231); catalogued as COSV54003379; called by muse, mutect2, varscan2
- NLRP5 | c.272C>T p.S91L | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated (0.78); PolyPhen benign (0.006); catalogued as rs774526318, COSV66765120; called by muse, mutect2, varscan2
- NLRP8 | c.1534G>A p.E512K | Missense Mutation (SNP) | VAF 48/198 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV52584212; called by muse, mutect2, varscan2
- NMUR2 | c.91G>A p.E31K | Missense Mutation (SNP) | VAF 42/159 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.01); catalogued as rs773720909, COSV54919913; called by muse, mutect2, varscan2
- NOL8 | c.1625C>T p.A542V | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.02); catalogued as rs749489755, COSV62635602; called by mutect2, varscan2
- NOP2 | c.1400G>A p.G467E (on ENST00000322166 / NM_001258308.2; = p.G463E on NM_006170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV59110904; called by muse, mutect2
- NOS1 | c.386C>T p.P129L | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.021); catalogued as COSV57613750; called by muse, varscan2
- NOTCH1 | c.1763C>T p.T588I | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); catalogued as COSV53056432; called by muse, mutect2, varscan2
- NOTCH4 | c.2024C>T p.S675F | Missense Mutation (SNP) | VAF 152/684 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); catalogued as rs1450662001, COSV66681141; called by muse, mutect2, varscan2
- NPAP1 | c.1330C>T p.L444F | Missense Mutation (SNP) | VAF 36/113 reads (32%) | SIFT tolerated (0.7); PolyPhen benign (0.031); catalogued as COSV61507634; called by muse, mutect2, varscan2
- NPAT | c.280T>A p.S94T | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.76); catalogued as COSV53718385; called by muse, mutect2, varscan2
- NPY4R | c.140C>T p.S47F | Missense Mutation (SNP) | VAF 24/250 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.02); catalogued as rs782024830, COSV65398029; called by muse, mutect2
- NRP1 | c.2056C>T p.H686Y | Missense Mutation (SNP) | VAF 48/196 reads (24%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.984); catalogued as COSV55168310; called by muse, mutect2, varscan2
- NRSN1 | c.470G>A p.R157Q | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.535); catalogued as rs557874546, COSV65893945; called by muse, mutect2, varscan2
- NRXN1 | c.2842G>A p.D948N | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.32); PolyPhen benign (0.096); catalogued as COSV58457767; called by muse, mutect2, varscan2
- NUDCD3 | c.535C>T p.P179S | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.08); catalogued as COSV62649131; called by muse, mutect2, varscan2
- NUTM1 | c.1943G>A p.G648E | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.012); catalogued as COSV59217126; called by muse, mutect2, varscan2
- OAS3 | c.1119T>G p.N373K | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.36); PolyPhen benign (0.005); catalogued as COSV57446201; called by muse, mutect2, varscan2
- OBP2A | c.226C>T p.Q76* | Nonsense Mutation (SNP) | VAF 15/96 reads (16%) | catalogued as COSV59792212; called by muse, mutect2, varscan2
- OGFOD3 | c.641T>C p.I214T | Missense Mutation (SNP) | VAF 23/38 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV57341349; called by muse, mutect2, varscan2
- OIP5 | c.427C>T p.P143S | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.54); PolyPhen benign (0.007); catalogued as COSV55033728; called by muse, mutect2, varscan2
- OPN1SW | c.5G>A p.R2K | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV50821984, COSV50823619; called by muse, mutect2, varscan2
- OPTC | c.506G>A p.R169K | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.038); catalogued as COSV65867902; called by muse, mutect2, varscan2
- OR10G8 | c.535G>A p.D179N | Missense Mutation (SNP) | VAF 37/105 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV70908633; called by muse, mutect2, varscan2
- OR13J1 | c.737C>T p.A246V | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.673); catalogued as rs1165205237, COSV65069835; called by muse, mutect2, varscan2
- OR1N2 | c.856C>T p.P286S | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs867542383, COSV65460539; called by muse, mutect2, varscan2
- OR2A14 | c.796C>T p.P266S | Missense Mutation (SNP) | VAF 44/209 reads (21%) | SIFT tolerated (0.48); PolyPhen benign (0.023); catalogued as COSV68718230; called by muse, varscan2
- OR2A25 | c.506G>A p.G169E | Missense Mutation (SNP) | VAF 72/204 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.623); catalogued as COSV68717294, COSV68717296; called by muse, mutect2, varscan2
- OR2F2 | c.208G>A p.D70N | Missense Mutation (SNP) | VAF 116/323 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs749732316, COSV68832689; called by muse, mutect2, varscan2
- OR2L2 | c.535G>A p.D179N | Missense Mutation (SNP) | VAF 109/226 reads (48%) | SIFT tolerated (0.12); PolyPhen benign (0.182); catalogued as COSV63553806; called by muse, mutect2, varscan2
- OR2T6 | c.429G>A p.M143I | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV63216461; called by muse, mutect2, varscan2
- OR4D5 | c.269C>T p.P90L | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.045); catalogued as COSV58307304; called by muse, mutect2, varscan2
- OR4K14 | c.168C>A p.H56Q | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.125); catalogued as COSV59293028; called by muse, mutect2, varscan2
- OR4K2 | c.243G>A p.M81I | Missense Mutation (SNP) | VAF 30/149 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); catalogued as rs1288967692, COSV53849761; called by muse, mutect2, varscan2
- OR4M1 | c.767C>T p.S256F | Missense Mutation (SNP) | VAF 15/117 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.332); catalogued as COSV60061707; called by muse, mutect2, varscan2
- OR51G2 | c.865C>T p.P289S | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV58991807; called by muse, mutect2
- OR5H6 | c.548C>T p.T183I (on ENST00000642105; = p.T167I on NM_001005479.2) | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.461); catalogued as COSV101051753; called by muse, mutect2, varscan2
- OR5I1 | c.341C>T p.S114F | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV56887263; called by muse, mutect2, varscan2
- OR5M1 | c.919G>A p.G307R | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs758063717, COSV101591606, COSV73202170; called by muse, mutect2, varscan2
- OR5W2 | c.154G>A p.D52N | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.12); catalogued as COSV100747566, COSV60616389; called by muse, mutect2, varscan2
- OR6C4 | c.185G>A p.R62Q | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.02); catalogued as rs762612300, COSV67793177; called by muse, mutect2, varscan2
- OR6C75 | c.662G>A p.R221Q | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.009); catalogued as rs541119837, COSV58552392; called by muse, mutect2, varscan2
- OR9K2 | c.25C>T p.H9Y | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.001); catalogued as COSV59532148; called by muse, mutect2, varscan2
- OSBP | c.1201A>T p.T401S | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV55663274; called by muse, mutect2, varscan2
- OSBPL1A | c.1141C>G p.L381V | Missense Mutation (SNP) | VAF 33/156 reads (21%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV60198910; called by muse, mutect2, varscan2
- OSBPL6 | c.1520C>T p.S507L | Missense Mutation (SNP) | VAF 26/117 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as COSV51919660; called by muse, mutect2, varscan2
- OTOA | c.1135G>A p.G379S (on ENST00000286149; = p.G365S on NM_144672.4) | Missense Mutation (SNP) | VAF 32/99 reads (32%) | SIFT tolerated (0.53); PolyPhen benign (0.03); catalogued as COSV53755722; called by muse, mutect2, varscan2
- OTOF | c.643G>A p.G215R | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV55505143; called by muse, mutect2, varscan2
- OTUD4 | c.998C>T p.P333L (on ENST00000447906 / NM_001366057.1; = p.P268L on NM_001102653.1) | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as COSV71381915; called by muse, mutect2, varscan2
- OVCH1 | c.1997C>T p.A666V | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV58963548; called by muse, mutect2, varscan2
- P4HA1 | c.1015C>T p.R339C | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.962); catalogued as COSV54958018; called by muse, mutect2, varscan2
- PAIP1 | c.926C>T p.S309F | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV59086179; called by muse, mutect2, varscan2
- PAK5 | c.1187C>T p.S396F | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.556); catalogued as COSV62028926; called by muse, mutect2, varscan2
- PAPPA2 | c.5266G>A p.G1756R | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752563091, COSV62799193; called by muse, mutect2, varscan2
- PASD1 | c.2212G>A p.D738N | Missense Mutation (SNP) | VAF 58/104 reads (56%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.015); catalogued as rs868089742, COSV100949569, COSV64855582; called by muse, mutect2, varscan2
- PCDH15 | c.4577A>C p.N1526T (on ENST00000617271 / NM_001142770.3; = p.K1514N on NM_001142769.3) | Missense Mutation (SNP) | VAF 45/174 reads (26%) | PolyPhen benign (0); catalogued as COSV64699159; called by muse, mutect2, varscan2
- PCDHA1 | c.619G>A p.E207K | Missense Mutation (SNP) | VAF 50/99 reads (51%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.406); catalogued as rs1462197146, COSV65374720; called by muse, mutect2, varscan2
- PCDHA4 | c.1828G>A p.E610K | Missense Mutation (SNP) | VAF 68/139 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.545); catalogued as COSV63538929; called by muse, mutect2, varscan2
- PCDHA5 | c.1815G>A p.W605* | Nonsense Mutation (SNP) | VAF 33/136 reads (24%) | catalogued as COSV65352900; called by muse, mutect2, varscan2
- PDE6A | c.568G>A p.A190T | Missense Mutation (SNP) | VAF 24/125 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV54927914; called by muse, mutect2, varscan2
- PDHA2 | c.331C>T p.H111Y | Missense Mutation (SNP) | VAF 34/140 reads (24%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.989); catalogued as COSV54777427; called by muse, mutect2, varscan2
- PDK3 | c.421C>T p.P141S | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated (0.13); PolyPhen benign (0.062); catalogued as COSV64793568; called by muse, mutect2, varscan2
- PELI1 | c.533G>A p.G178E | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.876); catalogued as rs1485158605, COSV62730136; called by muse, mutect2, varscan2
- PGLYRP2 | c.82G>A p.D28N | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.439); catalogued as COSV52994428; called by muse, mutect2, varscan2
- PGM2 | c.951T>G p.I317M | Missense Mutation (SNP) | VAF 34/121 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.739); catalogued as COSV67938966; called by muse, mutect2, varscan2
- PHLDB2 | c.77C>T p.S26F | Missense Mutation (SNP) | VAF 33/111 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.915); catalogued as COSV67311950, COSV67315678; called by muse, mutect2, varscan2
- PICK1 | c.212C>T p.T71I | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0.055); catalogued as COSV63660819; called by muse, mutect2, varscan2
- PIGL | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.056); catalogued as rs150000731; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PITPNM1 | c.3436G>A p.G1146S | Missense Mutation (SNP) | VAF 44/149 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54160323, COSV54160848; called by muse, mutect2, varscan2
- PLA2G4A | c.949G>A p.E317K | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.538); catalogued as COSV66554377; called by muse, mutect2, varscan2
- PLXNB1 | c.2557G>T p.D853Y | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.44); catalogued as COSV99602479; called by mutect2, varscan2
- PMFBP1 | c.1114G>A p.D372N | Missense Mutation (SNP) | VAF 21/108 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV52825254; called by muse, mutect2, varscan2
- POLD2 | c.716C>T p.S239F | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.959); catalogued as COSV56258387; called by muse, mutect2, varscan2
- POLD3 | c.455C>T p.S152F | Missense Mutation (SNP) | VAF 30/107 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.255); catalogued as rs1473340397, COSV55242999; called by muse, mutect2, varscan2
- POLH | c.1928C>T p.P643L | Missense Mutation (SNP) | VAF 45/264 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs755487113, COSV64779686; called by muse, mutect2, varscan2
- POU5F1 | c.503G>A p.G168E | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV52563881; called by muse, mutect2, varscan2
- PPBP | c.56C>T p.A19V | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV56019832; called by muse, mutect2, varscan2
- PPIF | c.376C>T p.P126S | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.281); catalogued as COSV56551248; called by muse, mutect2, varscan2
- PPIG | c.378-1G>A p.X126_splice | Splice Site (SNP) | VAF 24/79 reads (30%) | catalogued as COSV53643542; called by muse, mutect2, varscan2
- PPP4R4 | c.382C>T p.H128Y | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as rs267604106, COSV100175603; called by muse, mutect2, varscan2
- PPRC1 | c.559G>T p.G187W | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53385779, COSV53385800; called by muse, mutect2, varscan2
- PRB2 | c.731G>A p.G244E | Missense Mutation (SNP) | VAF 94/562 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as rs753828341, COSV66982746; called by muse, varscan2
- PRDM1 | c.508G>A p.E170K | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as COSV64844384; called by muse, mutect2, varscan2
- PRKAA2 | c.832C>T p.P278S | Missense Mutation (SNP) | VAF 33/153 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64802460; called by muse, mutect2, varscan2
- PRKCE | c.1795G>C p.E599Q | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100077122, COSV60314142; called by muse, mutect2, varscan2
- PRPF3 | c.517C>T p.P173S | Missense Mutation (SNP) | VAF 41/104 reads (39%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV100254595; called by muse, mutect2, varscan2
- PRPF3 | c.518C>T p.P173L | Missense Mutation (SNP) | VAF 42/105 reads (40%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs1271540038, COSV100254596; called by muse, mutect2, varscan2
- PRR5-ARHGAP8 | c.1448G>A p.R483Q (on ENST00000352766; = p.R404Q on NM_181334.5) | Missense Mutation (SNP) | VAF 46/190 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as rs373604411, COSV61236199; called by muse, mutect2, varscan2
- PRSS3 | c.202C>T p.P68S (on ENST00000361005 / NM_007343.4; = p.P176S on NM_002771.3) | Missense Mutation (SNP) | VAF 37/149 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.887); catalogued as COSV61556367, COSV99048473; called by muse, mutect2, varscan2
- PRUNE2 | c.3197C>T p.S1066F | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV65042174; called by muse, mutect2, varscan2
- PSG2 | c.865C>T p.P289S | Missense Mutation (SNP) | VAF 32/165 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.113); catalogued as rs574792687, COSV61545436; called by muse, mutect2, varscan2
- PSG9 | c.787G>A p.E263K | Missense Mutation (SNP) | VAF 100/342 reads (29%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as COSV52485385; called by muse, mutect2, varscan2
- PTGER2 | c.662A>G p.N221S | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.51); PolyPhen benign (0.031); catalogued as rs753753441, COSV55419044; called by muse, mutect2, varscan2
- PTPRC | c.1343A>T p.N448I | Missense Mutation (SNP) | VAF 39/78 reads (50%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.446); catalogued as COSV61412935; called by muse, mutect2, varscan2
- PTPRH | c.1240C>T p.P414S | Missense Mutation (SNP) | VAF 36/105 reads (34%) | SIFT tolerated (0.87); PolyPhen benign (0.01); catalogued as COSV54744132; called by muse, mutect2, varscan2
- PTPRN | c.2062G>A p.D688N | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs142270672, COSV55348681; called by muse, mutect2, varscan2
- QSER1 | c.2363C>T p.P788L (on ENST00000399302; = p.P917L on NM_001076786.3) | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.024); catalogued as COSV67899879; called by muse, mutect2, varscan2
- RAB27A | c.473C>T p.P158L | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.662); catalogued as COSV61016011; called by muse, mutect2, varscan2
- RAC2 | c.*1G>A | Splice Region (SNP) | VAF 10/30 reads (33%) | catalogued as COSV50774386; called by muse, mutect2, varscan2
- RAD17 | c.1309-2A>T p.X437_splice (on ENST00000380774 / NM_133339.2; = p.X426_splice on NM_002873.1) | Splice Site (SNP) | VAF 15/68 reads (22%) | catalogued as COSV51458055; called by muse, mutect2, varscan2
- RALGAPA2 | c.3355C>T p.P1119S | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.178); catalogued as COSV52499630; called by muse, mutect2
- RASGRP1 | c.883A>T p.M295L | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV60365482; called by muse, mutect2, varscan2
- RBMXL1 | c.623C>T p.S208F | Missense Mutation (SNP) | VAF 39/181 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as COSV53101794; called by muse, mutect2, varscan2
- REG1A | c.339G>A p.W113* | Nonsense Mutation (SNP) | VAF 17/71 reads (24%) | catalogued as COSV52069923; called by muse, mutect2, varscan2
- RERG | c.215G>A p.G72E | Missense Mutation (SNP) | VAF 113/460 reads (25%) | SIFT tolerated (0.79); PolyPhen benign (0.012); catalogued as COSV57001545; called by muse, mutect2, varscan2
- RETREG3 | c.974C>T p.S325F | Missense Mutation (SNP) | VAF 15/116 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1354356326, COSV53817374; called by muse, mutect2, varscan2
- RFPL3 | c.737G>A p.G246E (on ENST00000249007 / NM_001098535.1; = p.G217E on NM_006604.2) | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs568480601, COSV50749456; called by muse, mutect2, varscan2
- RFX4 | c.1233+2T>C p.X411_splice (on ENST00000392842 / NM_213594.3; = p.X317_splice on NM_032491.6) | Splice Site (SNP) | VAF 24/81 reads (30%) | catalogued as COSV57576362; called by muse, mutect2, varscan2
- RHBDD1 | c.889T>C p.F297L | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.086); catalogued as COSV58127416; called by muse, mutect2, varscan2
- RNF17 | c.4640T>G p.L1547R | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.685); catalogued as COSV55041580; called by muse, mutect2, varscan2
- RNF217 | c.1469G>A p.R490Q (on ENST00000521654 / NM_001286398.2; = p.R198Q on NM_152553.5) | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs753807024, COSV51576066; called by muse, mutect2, varscan2
- ROBO1 | c.4525C>T p.P1509S | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV71395040; called by muse, mutect2, varscan2
- ROR2 | c.2191G>A p.E731K | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as rs757252249, COSV65216326; called by muse, mutect2, varscan2
- RPGRIP1 | c.2405G>A p.W802* | Nonsense Mutation (SNP) | VAF 11/38 reads (29%) | catalogued as COSV52850835; called by muse, mutect2, varscan2
- RPS20 | c.92C>T p.S31F | Missense Mutation (SNP) | VAF 27/162 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.141); catalogued as COSV50536536; called by muse, mutect2, varscan2
- RPTN | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.755); catalogued as COSV60166496; called by muse, mutect2, varscan2
- RSPH10B | c.2433-1G>A p.X811_splice | Splice Site (SNP) | VAF 26/73 reads (36%) | catalogued as COSV100382734; called by muse, mutect2, varscan2
- RSPH4A | c.275C>T p.S92F | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0.003); catalogued as COSV57635202; called by muse, mutect2, varscan2
- RSPH9 | c.697G>C p.G233R | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100928702; called by muse, mutect2, varscan2
- RSPH9 | c.698G>A p.G233D | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100928703; called by muse, mutect2, varscan2
- RTCA | c.38T>C p.M13T | Missense Mutation (SNP) | VAF 31/96 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.18); catalogued as rs755406238, COSV53120737; called by muse, mutect2, varscan2
- SACS | c.10036C>T p.P3346S | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.617); catalogued as COSV66540837; called by muse, mutect2, varscan2
- SAMD9 | c.931C>T p.P311S | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV66075859; called by muse, mutect2, varscan2
- SAXO1 | c.1399C>T p.Q467* | Nonsense Mutation (SNP) | VAF 41/163 reads (25%) | catalogued as rs747905247, COSV65870364; called by muse, mutect2, varscan2
- SCFD2 | c.1274G>A p.W425* | Nonsense Mutation (SNP) | VAF 25/68 reads (37%) | catalogued as COSV66372230; called by muse, mutect2, varscan2
- SCN11A | c.2801C>T p.A934V | Missense Mutation (SNP) | VAF 50/191 reads (26%) | SIFT tolerated (0.53); PolyPhen benign (0.007); catalogued as COSV56571436; called by muse, mutect2, varscan2
- SCN3A | c.3166G>A p.E1056K | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.038); catalogued as COSV51811807, COSV51825859, COSV99325458; called by muse, mutect2, varscan2
- SCN3A | c.2384G>A p.G795E | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV51811827; called by muse, mutect2, varscan2
- SCNN1B | c.980C>T p.P327L | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100225678, COSV56305198; called by muse, mutect2, varscan2
- SDR16C5 | c.352G>A p.D118N | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); catalogued as rs755734218, COSV58126752; called by muse, mutect2, varscan2
- SEC14L4 | c.994G>A p.E332K | Missense Mutation (SNP) | VAF 32/130 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.142); catalogued as rs1360418409, COSV55400008; called by muse, mutect2, varscan2
- SEC16A | c.712C>T p.P238S | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.138); catalogued as COSV51529435; called by muse, mutect2, varscan2
- SEC63 | c.1360T>C p.L454= | Splice Region (SNP) | VAF 45/108 reads (42%) | catalogued as COSV64600114; called by muse, mutect2, varscan2
- SEMG2 | c.1034A>C p.K345T | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.955); catalogued as COSV65647541; called by muse, mutect2, varscan2
- SERPINA3 | c.463G>A p.E155K | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.06); catalogued as COSV101261639; called by muse, mutect2, varscan2
- SERPINC1 | c.352G>A p.A118T | Missense Mutation (SNP) | VAF 32/116 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV62929606; called by muse, mutect2, varscan2
- SH2D1B | c.241G>A p.E81K | Missense Mutation (SNP) | VAF 39/93 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as COSV63392299; called by muse, mutect2, varscan2
- SH3TC1 | c.2089G>A p.D697N | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0.236); catalogued as rs940337971, COSV99794555; called by muse, varscan2
- SIRPG | c.212G>A p.G71E | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.852); catalogued as COSV53807827; called by muse, mutect2, varscan2
- SLC11A2 | c.1454C>T p.P485L (on ENST00000394904 / NM_001379455.1; = p.P456L on NM_000617.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50371137; called by muse, mutect2, varscan2
- SLC15A3 | c.934G>T p.V312L | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.682); catalogued as COSV57171960; called by muse, mutect2, varscan2
- SLC17A8 | c.1579G>A p.E527K | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.028); catalogued as rs755212082, COSV60121740; called by muse, mutect2, varscan2
- SLC25A21 | c.224G>A p.G75E | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780255591, COSV58723097; called by muse, mutect2
- SLC2A14 | c.1268C>T p.P423L | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.208); catalogued as COSV100533647; called by muse, mutect2, varscan2
- SLC2A14 | c.1267C>T p.P423S | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.466); catalogued as COSV100533649, COSV100533809; called by muse, mutect2, varscan2
- SLC33A1 | c.485T>A p.V162E | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV63947214; called by muse, mutect2, varscan2
- SLC38A4 | c.449G>A p.G150E | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV56964792; called by muse, mutect2, varscan2
- SLC43A1 | c.565T>C p.Y189H | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53559240; called by muse, mutect2, varscan2
- SLC5A8 | c.928C>T p.P310S | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV73310725; called by muse, mutect2, varscan2
- SLCO1B3 | c.865G>A p.E289K | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.088); catalogued as COSV53938763, COSV53947461; called by muse, mutect2, varscan2
- SLCO1B3 | c.1683-1G>A p.X561_splice | Splice Site (SNP) | VAF 6/40 reads (15%) | catalogued as COSV53931714, COSV99681463; called by muse, mutect2, varscan2
- SLCO1C1 | c.625A>T p.I209F | Missense Mutation (SNP) | VAF 34/94 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.856); catalogued as COSV56873552; called by muse, mutect2, varscan2
- SLCO5A1 | c.1154C>T p.S385F | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.627); catalogued as COSV52660563; called by muse, mutect2, varscan2
- SLCO6A1 | c.53G>A p.G18E | Missense Mutation (SNP) | VAF 150/309 reads (49%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs112814311, COSV65810757; called by muse, mutect2, varscan2
- SMAD9 | c.1202G>A p.G401D (on ENST00000379826 / NM_001127217.3; = p.G364D on NM_005905.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV63205092; called by muse, mutect2, varscan2
- SMOC1 | c.556G>A p.E186K | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV62761456; called by muse, mutect2, varscan2
- SMPD3 | c.457G>A p.E153K | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.679); catalogued as rs770637916, COSV54712883; called by muse, mutect2, varscan2
- SMU1 | c.1036C>T p.R346C | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.427); catalogued as COSV68139475; called by muse, mutect2, varscan2
- SMYD1 | c.1363G>A p.E455K | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.147); catalogued as rs770519021, COSV70225276; called by muse, mutect2, varscan2
- SORCS3 | c.2387T>C p.I796T | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.366); catalogued as COSV63795491; called by muse, mutect2, varscan2
- SPANXD | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 123/213 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs1180897900, COSV65152248, COSV65152621; called by muse, mutect2, varscan2
- SPHK2 | c.823C>T p.P275S | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55338015; called by muse, mutect2, varscan2
- SPHKAP | c.3826C>T p.P1276S | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); catalogued as COSV60881435; called by muse, mutect2, varscan2
- SPI1 | c.22G>A p.E8K | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV57045935; called by muse, mutect2
- SPOCK3 | c.1180G>A p.D394N | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated, low confidence (0.18); PolyPhen probably damaging (0.99); catalogued as rs141348000, COSV62727097; called by muse, mutect2, varscan2
- SPOPL | c.254C>T p.S85F | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54513822; called by muse, mutect2, varscan2
- SPRY3 | c.469C>T p.P157S | Missense Mutation (SNP) | VAF 28/126 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as COSV100249475, COSV57143222; called by muse, mutect2, varscan2
- SPTBN5 | c.9178C>T p.Q3060* | Nonsense Mutation (SNP) | VAF 12/30 reads (40%) | catalogued as COSV58021976; called by muse, mutect2, varscan2
- SRCAP | c.3314C>T p.S1105F | Missense Mutation (SNP) | VAF 39/161 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.459); catalogued as COSV52673636; called by muse, mutect2, varscan2
- SRD5A2 | c.557T>C p.F186S | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51871780; called by muse, mutect2, varscan2
- SRF | c.1255C>T p.P419S | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT tolerated (0.45); PolyPhen benign (0.039); catalogued as COSV52729421; called by muse, mutect2, varscan2
- SRGN | c.361C>T p.Q121* | Nonsense Mutation (SNP) | VAF 10/45 reads (22%) | catalogued as COSV54344921; called by muse, mutect2, varscan2
- SRPK2 | c.1340A>T p.E447V | Missense Mutation (SNP) | VAF 45/118 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.039); catalogued as rs1438961969, COSV61961411; called by muse, mutect2, varscan2
- SSX1 | c.23C>A p.A8E | Missense Mutation (SNP) | VAF 33/52 reads (63%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as COSV65355638; called by muse, mutect2, varscan2
- ST18 | c.676C>T p.H226Y | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.024); catalogued as COSV52495900; called by muse, mutect2, varscan2
- STAB2 | c.1360T>G p.F454V | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.394); catalogued as COSV66340093; called by muse, mutect2, varscan2
- STAT2 | c.811C>T p.H271Y | Missense Mutation (SNP) | VAF 46/181 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as COSV58475835; called by muse, mutect2, varscan2
- STC1 | c.206G>A p.G69E | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51688682; called by muse, mutect2, varscan2
- STON2 | c.139G>A p.E47K | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1404525096, COSV50845595; called by muse, mutect2, varscan2
- STPG2 | c.934G>A p.E312K | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.92); PolyPhen benign (0.003); catalogued as COSV54783332; called by muse, varscan2
- SUCNR1 | c.67A>T p.K23* | Nonsense Mutation (SNP) | VAF 15/70 reads (21%) | catalogued as COSV62912306; called by muse, mutect2, varscan2
- SUGP1 | c.440C>T p.S147F | Missense Mutation (SNP) | VAF 34/55 reads (62%) | SIFT deleterious (0); PolyPhen benign (0.216); catalogued as COSV55921967; called by muse, mutect2, varscan2
- SULF1 | c.2206G>A p.G736R | Missense Mutation (SNP) | VAF 30/126 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.071); catalogued as COSV52683020; called by muse, mutect2, varscan2
- SULF1 | c.2377T>G p.F793V | Missense Mutation (SNP) | VAF 35/124 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52683037; called by muse, mutect2, varscan2
- SULT1C4 | c.475C>T p.P159S | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.942); catalogued as COSV55598037; called by muse, mutect2, varscan2
- TANGO6 | c.886C>T p.R296W | Missense Mutation (SNP) | VAF 41/135 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.425); catalogued as rs538301430, COSV55766329; called by muse, mutect2, varscan2
- TAOK1 | c.2866C>T p.R956* | Nonsense Mutation (SNP) | VAF 20/43 reads (47%) | catalogued as rs1165032002, COSV55592553; called by muse, mutect2, varscan2
- TAOK2 | c.3532C>T p.H1178Y | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.047); catalogued as COSV54230248; called by muse, mutect2, varscan2
- TARS2 | c.463C>T p.P155S | Missense Mutation (SNP) | VAF 86/192 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.154); catalogued as COSV64695633; called by muse, mutect2, varscan2
- TAT | c.538G>A p.G180R | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63532967; called by muse, mutect2, varscan2
- TBXA2R | c.994C>T p.L332F | Missense Mutation (SNP) | VAF 12/17 reads (71%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.69); catalogued as rs1193074174, COSV59259228; called by muse, mutect2, varscan2
- TCF23 | c.479G>A p.R160Q | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs760896868, COSV56078055; called by muse, mutect2, varscan2
- TCHHL1 | c.1351G>A p.G451R | Missense Mutation (SNP) | VAF 63/151 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.144); catalogued as rs769842978, COSV64285965; called by muse, mutect2, varscan2
- TCP11 | c.658G>A p.E220K (on ENST00000512012; = p.E158K on NM_018679.5) | Missense Mutation (SNP) | VAF 79/298 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as COSV55132869; called by muse, mutect2, varscan2
- TENM1 | c.6359C>T p.A2120V | Missense Mutation (SNP) | VAF 15/21 reads (71%) | SIFT tolerated (0.5); PolyPhen benign (0.093); catalogued as COSV64433411; called by muse, mutect2, varscan2
- TENM3 | c.770G>A p.G257E | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV69309757; called by muse, mutect2
- TENM3 | c.2594C>T p.S865F | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.557); catalogued as COSV69309766; called by muse, varscan2
- TENM3 | c.2669C>T p.P890L | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as rs1037445796, COSV69298593, COSV69309771; called by muse, varscan2
- TFEB | c.344C>T p.P115L | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.886); catalogued as rs746642722, COSV100026383, COSV57823668; called by muse, mutect2
- TFPI | c.908A>G p.N303S | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.018); catalogued as COSV51901487; called by muse, mutect2
- THAP4 | c.980C>T p.S327F | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.32); catalogued as COSV67191738; called by muse, mutect2, varscan2
- THBS3 | c.2254-1G>A p.X752_splice | Splice Site (SNP) | VAF 15/104 reads (14%) | catalogued as COSV64249586; called by muse, mutect2, varscan2
- THSD7A | c.3955C>T p.Q1319* | Nonsense Mutation (SNP) | VAF 6/19 reads (32%) | catalogued as COSV69855791; called by muse, mutect2, varscan2
- THSD7A | c.595G>A p.E199K | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.183); catalogued as rs760394880, COSV70265686; called by muse, varscan2
- THSD7B | c.1832C>T p.S611L | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); catalogued as rs748467463, COSV55693384; called by muse, mutect2, varscan2
- TIMP3 | c.260C>T p.S87F | Missense Mutation (SNP) | VAF 33/130 reads (25%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.999); catalogued as COSV56663352; called by muse, mutect2, varscan2
- TIMP4 | c.237+1G>A p.X79_splice | Splice Site (SNP) | VAF 12/232 reads (5%) | catalogued as COSV55139271; called by muse, mutect2
- TLN1 | c.6509C>T p.S2170F | Missense Mutation (SNP) | VAF 16/103 reads (16%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.636); catalogued as COSV59208046; called by muse, mutect2, varscan2
- TM9SF4 | c.1570-1G>A p.X524_splice | Splice Site (SNP) | VAF 14/57 reads (25%) | catalogued as COSV54107709; called by muse, mutect2, varscan2
- TMEM108 | c.1606-1G>A p.X536_splice | Splice Site (SNP) | VAF 20/85 reads (24%) | catalogued as COSV56589190; called by muse, mutect2, varscan2
- TMEM119 | c.149C>T p.S50F | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.066); catalogued as COSV101219439, COSV101219546; called by mutect2, varscan2
- TMEM178A | c.485C>T p.T162I | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.039); catalogued as rs1472774933, COSV56141978; called by muse, mutect2, varscan2
- TMEM209 | c.605C>T p.P202L | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.218); catalogued as rs754213345, COSV61021582; called by muse, mutect2, varscan2
- TMEM89 | c.163C>T p.P55S | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.135); catalogued as COSV56572489; called by muse, mutect2, varscan2
- TMIGD1 | c.443A>G p.N148S | Missense Mutation (SNP) | VAF 72/171 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV61028674; called by muse, mutect2, varscan2
- TNC | c.5452A>G p.R1818G | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated (0.35); PolyPhen benign (0.18); catalogued as COSV60785537; called by muse, mutect2, varscan2
- TNFAIP6 | c.571G>A p.D191N | Missense Mutation (SNP) | VAF 23/115 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs866337628, COSV54641073; called by muse, mutect2, varscan2
- TNIP3 | c.801del p.C268Vfs*53 | Frame Shift Del (DEL) | VAF 3/21 reads (14%) | catalogued as rs750188457; called by mutect2, pindel
- TNN | c.1108G>A p.E370K | Missense Mutation (SNP) | VAF 38/79 reads (48%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.803); catalogued as COSV53427392; called by muse, mutect2, varscan2
- TPO | c.826G>A p.E276K | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.85); PolyPhen benign (0.173); catalogued as COSV61103030; called by muse, mutect2
- TRABD2A | c.268C>T p.L90F | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs868277440, COSV59103524; called by muse, mutect2, varscan2
- TRANK1 | c.8534C>T p.S2845L | Missense Mutation (SNP) | VAF 25/103 reads (24%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs749947789, COSV57152447; called by muse, mutect2, varscan2
- TRHDE | c.2854G>A p.G952R | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53846773; called by muse, mutect2, varscan2
- TRIM58 | c.1454A>T p.H485L | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV63570570; called by muse, mutect2
- TRPM3 | c.4936G>A p.E1646K (on ENST00000357533 / NM_001366142.2; = p.E1501K on NM_020952.6) | Missense Mutation (SNP) | VAF 142/514 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.034); catalogued as COSV62586318, COSV62587209; called by muse, mutect2, varscan2
- TRPM3 | c.1662G>A p.W554* (on ENST00000357533 / NM_001366142.2; = p.W399* on NM_024971.6) | Nonsense Mutation (SNP) | VAF 17/87 reads (20%) | catalogued as COSV100676906; called by muse, mutect2
- TRPM8 | c.1096G>A p.V366M | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.115); catalogued as rs779493711, COSV61222263; called by muse, mutect2, varscan2
- TSHZ2 | c.938C>T p.S313F | Missense Mutation (SNP) | VAF 27/107 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV61589105; called by muse, mutect2, varscan2
- TTC17 | c.553C>T p.L185F | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV50009424; called by muse, mutect2, varscan2
- TTN | c.71950C>T p.P23984S (on ENST00000591111; = p.P16560S on NM_003319.4) | Missense Mutation (SNP) | VAF 29/122 reads (24%) | PolyPhen possibly damaging (0.897); catalogued as COSV60105120; called by muse, mutect2, varscan2
- TTN | c.32393C>T p.P10798L (on ENST00000591111; = p.P9871L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/89 reads (30%) | PolyPhen benign (0.006); catalogued as rs1060500394, COSV60105141; called by muse, mutect2, varscan2
- TTN | c.21634G>A p.G7212R (on ENST00000591111; = p.G6285R on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/64 reads (22%) | PolyPhen probably damaging (1); catalogued as COSV60105149; called by muse, mutect2, varscan2
- TTN | c.12137C>T p.P4046L (on ENST00000591111; = p.P4000L on NM_003319.4) | Missense Mutation (SNP) | VAF 5/22 reads (23%) | catalogued as COSV100600183; called by muse, mutect2, varscan2
- TTN | c.626C>T p.S209L | Missense Mutation (SNP) | VAF 24/48 reads (50%) | PolyPhen probably damaging (0.947); catalogued as rs372632047; ClinVar: uncertain significance; called by muse, varscan2
- TUB | c.154C>T p.R52W | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs150936269; called by muse, mutect2
- TXK | c.1388G>A p.G463E | Missense Mutation (SNP) | VAF 23/118 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755294001, COSV51912114, COSV51912661; called by muse, mutect2, varscan2
- TXNDC16 | c.2374A>T p.I792F | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT tolerated (0.48); PolyPhen benign (0.154); catalogued as COSV55984989; called by muse, mutect2, varscan2
- UBQLNL | c.278G>T p.G93V | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV66493610; called by muse, mutect2, varscan2
- UBR1 | c.2827C>T p.H943Y | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV51930586, COSV99316742; called by muse, mutect2, varscan2
- UBXN2A | c.285G>A p.K95= | Splice Region (SNP) | VAF 12/44 reads (27%) | catalogued as COSV100465353, COSV58336618; called by mutect2, varscan2
- UGT1A1 | c.1028C>T p.S343L | Missense Mutation (SNP) | VAF 32/165 reads (19%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.509); catalogued as rs144978321; called by muse, mutect2, varscan2
- UGT1A4 | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.097); catalogued as COSV100529910; called by muse, mutect2, varscan2
- UGT2B10 | c.779C>T p.S260F | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV55321006; called by muse, mutect2, varscan2
- UNC13A | c.1180G>A p.E394K | Missense Mutation (SNP) | VAF 14/21 reads (67%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.053); catalogued as rs529698632, COSV53197563; called by muse, mutect2
- UNC13B | c.908C>T p.S303F | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.052); catalogued as COSV65935264; called by muse, mutect2, varscan2
- UNC13B | c.1429C>T p.P477S | Missense Mutation (SNP) | VAF 51/154 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.655); catalogued as rs367581284; called by muse, mutect2, varscan2
- UQCRFS1 | c.341C>T p.S114F | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.981); catalogued as COSV59184980, COSV59184989; called by muse, mutect2, varscan2
- USP19 | c.123A>G p.K41= | Splice Region (SNP) | VAF 31/150 reads (21%) | catalogued as COSV59734136; called by muse, mutect2, varscan2
- USP25 | c.878A>G p.N293S | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as COSV53485118; called by muse, mutect2, varscan2
- USP29 | c.1743G>A p.M581I | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs868757028, COSV54143346; called by muse, mutect2, varscan2
- USP33 | c.2495T>A p.I832N | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.065); catalogued as COSV62469751; called by muse, mutect2, varscan2
- USP44 | c.32G>A p.G11E | Missense Mutation (SNP) | VAF 27/122 reads (22%) | SIFT tolerated (0.49); PolyPhen benign (0.12); catalogued as COSV51564391; called by muse, mutect2, varscan2
- VANGL2 | c.866C>T p.A289V | Missense Mutation (SNP) | VAF 27/118 reads (23%) | SIFT tolerated (0.45); PolyPhen benign (0.013); catalogued as COSV63604594; called by muse, mutect2, varscan2
- VEGFC | c.233G>A p.W78* | Nonsense Mutation (SNP) | VAF 4/22 reads (18%) | catalogued as COSV54598907; called by muse, mutect2, varscan2
- VPS13A | c.481C>T p.R161C | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62428496; called by muse, mutect2, varscan2
- VPS13B | c.12053G>A p.R4018K | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.446); catalogued as COSV99881840, COSV99881878; called by muse, mutect2, varscan2
- VPS36 | c.1102C>T p.R368C | Missense Mutation (SNP) | VAF 63/231 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs778431031, COSV65199284; called by muse, mutect2, varscan2
- VRTN | c.1117G>A p.E373K | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.012); catalogued as rs570547691, COSV56441362; called by muse, mutect2, varscan2
- VTCN1 | c.688G>A p.D230N | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs762487536, COSV60223723, COSV60224445; called by muse, mutect2, varscan2
- WFIKKN2 | c.1678G>A p.V560I | Missense Mutation (SNP) | VAF 44/117 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.096); catalogued as rs1453998863, COSV60958958; called by muse, mutect2, varscan2
- WRNIP1 | c.1643-1G>T p.X548_splice | Splice Site (SNP) | VAF 16/38 reads (42%) | catalogued as COSV66356103; called by muse, mutect2, varscan2
- WTIP | c.1055C>T p.S352F | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV54328578; called by muse, mutect2
- XIRP2 | c.1456A>T p.R486W (on ENST00000628543; = p.R661W on NM_152381.6) | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.715); catalogued as COSV54704477; called by muse, mutect2, varscan2
- ZBED9 | c.2486C>T p.P829L | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT tolerated, low confidence (0.72); PolyPhen probably damaging (0.995); catalogued as rs142639079; called by muse, mutect2, varscan2
- ZBTB7C | c.877G>A p.E293K | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as COSV59689056; called by muse, mutect2, varscan2
- ZBTB8A | c.901C>T p.L301F | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV57142750, COSV57143600; called by muse, mutect2, varscan2
- ZFHX3 | c.887C>T p.S296L | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1332687082, COSV51711855; called by muse, mutect2, varscan2
- ZFP90 | c.1474C>T p.P492S | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.158); catalogued as rs1207141472, COSV68050994; called by muse, mutect2, varscan2
- ZFPM2 | c.2375C>T p.P792L | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.321); catalogued as COSV65873583; called by muse, mutect2, varscan2
- ZNF239 | c.1193C>T p.T398I | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60018882; called by muse, mutect2, varscan2
- ZNF268 | c.1034C>T p.S345L | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as COSV57213066; called by muse, mutect2, varscan2
- ZNF280A | c.238C>T p.R80C | Missense Mutation (SNP) | VAF 36/122 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as rs751413057, COSV57480816; called by muse, mutect2, varscan2
- ZNF284 | c.764G>A p.G255E | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.771); catalogued as COSV69691135; called by muse, mutect2, varscan2
- ZNF425 | c.893G>A p.G298E | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.27); catalogued as COSV65201464; called by muse, varscan2
- ZNF425 | c.799G>A p.V267I | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT tolerated (0.36); PolyPhen benign (0.07); catalogued as COSV65201470; called by muse, varscan2
- ZNF426 | c.1650T>A p.H550Q | Missense Mutation (SNP) | VAF 33/61 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.589); catalogued as rs751249128, COSV53469402; called by muse, mutect2, varscan2
- ZNF438 | c.1465C>T p.P489S | Missense Mutation (SNP) | VAF 43/148 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.018); catalogued as COSV59196343, COSV59197000; called by muse, mutect2, varscan2
- ZNF518A | c.3448C>T p.P1150S | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT tolerated (0.46); PolyPhen benign (0.044); catalogued as COSV60151617; called by muse, mutect2, varscan2
- ZNF532 | c.1357C>T p.L453F | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV60173449; called by muse, mutect2, varscan2
- ZNF556 | c.388C>T p.R130* | Nonsense Mutation (SNP) | VAF 20/38 reads (53%) | catalogued as rs751805727, COSV56912090; called by muse, mutect2, varscan2
- ZNF577 | c.358C>T p.H120Y | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs770144779, COSV100030871; called by muse, mutect2, varscan2
- ZNF589 | c.992C>T p.S331L | Missense Mutation (SNP) | VAF 30/118 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.85); catalogued as rs200474615, COSV61220318, COSV61220487; called by muse, mutect2, varscan2
- ZNF620 | c.934G>A p.E312K | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs377575762, COSV100093965; called by muse, mutect2, varscan2
- ZNF750 | c.959G>A p.G320E | Missense Mutation (SNP) | VAF 115/256 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as COSV53958642; called by muse, mutect2, varscan2
- ZNF761 | c.1909G>A p.E637K | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.023); catalogued as COSV100483292; called by muse, mutect2, varscan2
- ZNF821 | c.647C>T p.S216F (on ENST00000425432 / NM_001376297.1; = p.S174F on NM_017530.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 31/95 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.809); catalogued as rs767370929, COSV57987530; called by muse, mutect2, varscan2
- ZPBP2 | c.215G>A p.W72* (on ENST00000348931 / NM_199321.3; = p.W50* on NM_198844.3) | Nonsense Mutation (SNP) | VAF 41/103 reads (40%) | catalogued as COSV62375324; called by muse, mutect2, varscan2
- ZSWIM1 | c.285C>A p.F95L | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.038); catalogued as COSV54848109; called by muse, mutect2, varscan2
- ZSWIM8 | c.1240C>T p.H414Y | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); catalogued as COSV67132786; called by muse, mutect2, varscan2
- AMIGO2 | c.1033_1048del p.N345* | Frame Shift Del (DEL) | VAF 20/110 reads (18%) | called by mutect2, pindel, varscan2
- ARHGEF15 | c.1181C>T p.T394I | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); called by muse, mutect2
- CPN2 | c.1156_1161del p.N386_L387del | In Frame Del (DEL) | VAF 15/70 reads (21%) | called by mutect2, pindel, varscan2
- IGHG2 | c.176C>T p.S59F | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- KIR2DS4 | c.605G>A p.G202D | Missense Mutation (SNP) | VAF 83/333 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- RBP3 | c.3595G>A p.G1199R | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- SNX32 | c.315_316insA p.E106Rfs*27 | Frame Shift Ins (INS) | VAF 26/78 reads (33%) | called by mutect2, varscan2
- SUPT6H | c.370dup p.M124Nfs*4 | Frame Shift Ins (INS) | VAF 38/84 reads (45%) | called by mutect2, varscan2
- TEP1 | c.2929del p.Y977Mfs*28 | Frame Shift Del (DEL) | VAF 31/149 reads (21%) | called by mutect2, pindel, varscan2
- TPTE | c.619C>T p.H207Y (on ENST00000618007 / NM_199261.4; = p.H189Y on NM_199259.4) | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.627); called by muse, mutect2, varscan2
- ZBTB34 | c.852del p.Y285Ifs*18 | Frame Shift Del (DEL) | VAF 10/53 reads (19%) | called by mutect2, pindel, varscan2
- AATF | c.1434C>T p.S478= | Silent (SNP) | VAF 40/101 reads (40%) | called by muse, mutect2, varscan2
- ABCA10 | c.1041C>T p.F347= | Silent (SNP) | VAF 40/82 reads (49%) | catalogued as COSV52223238; called by muse, mutect2, varscan2
- ABCC8 | c.3015C>T p.S1005= | Silent (SNP) | VAF 79/290 reads (27%) | catalogued as COSV56851496; called by muse, mutect2, varscan2
- ABHD8 | c.210G>A p.G70= | Silent (SNP) | VAF 9/40 reads (23%) | catalogued as COSV53112975; called by muse, mutect2, varscan2
- AC008676.3 | c.171G>A p.T57= | Silent (SNP) | VAF 74/174 reads (43%) | catalogued as rs746101731, COSV56635988; called by muse, mutect2, varscan2
- ACTB | c.795C>T p.S265= | Silent (SNP) | VAF 27/96 reads (28%) | catalogued as rs771436794, COSV100079339; called by muse, mutect2, varscan2
- ADAM7 | c.207C>T p.T69= | Silent (SNP) | VAF 15/44 reads (34%) | catalogued as rs533524343, COSV51540803; called by muse, mutect2
- ADAMTS15 | c.2094C>T p.F698= | Silent (SNP) | VAF 28/74 reads (38%) | catalogued as rs267602783, COSV54503735; called by muse, mutect2, varscan2
- ADAMTSL2 | c.1545G>A p.L515= | Silent (SNP) | VAF 14/54 reads (26%) | called by muse, mutect2, varscan2
- ADGRE1 | c.771G>A p.L257= | Silent (SNP) | VAF 16/68 reads (24%) | catalogued as COSV51672730, COSV99165027; called by muse, mutect2, varscan2
- ADGRF4 | c.1240C>T p.L414= | Silent (SNP) | VAF 19/64 reads (30%) | catalogued as rs372960643; called by muse, mutect2, varscan2
- ADGRG3 | c.1224C>T p.I408= | Silent (SNP) | VAF 12/53 reads (23%) | catalogued as COSV100342168; called by muse, mutect2, varscan2
- ADGRG4 | c.1947C>T p.F649= | Silent (SNP) | VAF 5/12 reads (42%) | catalogued as COSV54957645; called by muse, mutect2, varscan2
- ADGRL3 | c.3669G>A p.G1223= (on ENST00000506720 / NM_001322402.2; = p.G1155= on NM_015236.6) | Silent (SNP) | VAF 17/59 reads (29%) | catalogued as COSV72229439; called by muse, mutect2, varscan2
- ADGRV1 | c.7818G>A p.V2606= | Silent (SNP) | VAF 62/122 reads (51%) | catalogued as rs753621703, COSV67986507; called by muse, mutect2, varscan2
- ADGRV1 | c.12690G>A p.E4230= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as COSV101315612; called by muse, mutect2, varscan2
- ADORA3 | c.417C>T p.F139= | Silent (SNP) | VAF 29/129 reads (22%) | catalogued as COSV53985882; called by muse, mutect2, varscan2
- AFTPH | c.2065A>C p.R689= | Silent (SNP) | VAF 15/55 reads (27%) | catalogued as COSV53218505; called by muse, mutect2, varscan2
- AGBL2 | c.1959C>T p.S653= | Silent (SNP) | VAF 16/75 reads (21%) | catalogued as rs776809385, COSV54092606; called by muse, mutect2, varscan2
- AL645922.1 | c.1761G>A p.L587= | Silent (SNP) | VAF 94/478 reads (20%) | catalogued as COSV54960849; called by muse, mutect2, varscan2
- ANK1 | c.105G>A p.G35= | Silent (SNP) | VAF 100/539 reads (19%) | catalogued as COSV55883278; called by muse, mutect2, varscan2
- ANK3 | c.9627G>A p.E3209= | Silent (SNP) | VAF 16/51 reads (31%) | catalogued as COSV55061046; called by muse, mutect2, varscan2
- ANKEF1 | c.2289C>T p.I763= | Silent (SNP) | VAF 11/22 reads (50%) | catalogued as COSV101000996; called by muse, mutect2, varscan2
- ANKRD35 | c.1344G>A p.G448= | Silent (SNP) | VAF 58/121 reads (48%) | catalogued as COSV62910525; called by muse, mutect2, varscan2
- ANKS1A | c.345C>T p.Y115= | Silent (SNP) | VAF 30/74 reads (41%) | catalogued as COSV64461151; called by muse, mutect2, varscan2
- AOAH | c.1005G>A p.Q335= | Silent (SNP) | VAF 9/51 reads (18%) | catalogued as COSV51742373; called by muse, mutect2, varscan2
- AOC1 | c.1176G>A p.P392= | Silent (SNP) | VAF 55/154 reads (36%) | catalogued as rs748358249, COSV62868643; called by muse, mutect2, varscan2
- ATCAY | c.333G>A p.G111= | Silent (SNP) | VAF 47/94 reads (50%) | catalogued as COSV56656344; called by muse, mutect2, varscan2
- AVPR1B | c.366C>T p.T122= | Silent (SNP) | VAF 31/115 reads (27%) | catalogued as COSV65638182; called by muse, mutect2, varscan2
- B3GNT2 | c.957G>C p.L319= | Silent (SNP) | VAF 29/92 reads (32%) | catalogued as COSV57344798; called by muse, mutect2, varscan2
- B4GALNT1 | c.723C>T p.S241= | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as rs1472859717, COSV57543062; called by muse, mutect2, varscan2
- BPIFA3 | c.43C>T p.L15= | Silent (SNP) | VAF 15/78 reads (19%) | catalogued as COSV64925925; called by muse, mutect2, varscan2
- C11orf80 | c.564C>T p.H188= | Silent (SNP) | VAF 6/31 reads (19%) | catalogued as rs1157479747, COSV60929493; called by muse, mutect2
- C3 | c.2235C>T p.G745= | Silent (SNP) | VAF 30/43 reads (70%) | catalogued as COSV55574057; called by muse, mutect2, varscan2
- CACNA1A | c.4713C>T p.F1571= | Silent (SNP) | VAF 29/56 reads (52%) | catalogued as rs780277246, COSV64194548; called by muse, mutect2, varscan2
- CACNA1E | c.2613G>A p.R871= | Silent (SNP) | VAF 8/31 reads (26%) | catalogued as COSV62398643; called by muse, mutect2, varscan2
- CAD | c.6354C>T p.F2118= | Silent (SNP) | VAF 18/66 reads (27%) | catalogued as COSV53027173; called by muse, mutect2, varscan2
- CADM1 | c.672C>T p.H224= | Silent (SNP) | VAF 10/27 reads (37%) | catalogued as COSV59012051; called by muse, mutect2, varscan2
- CADPS2 | c.3729G>A p.R1243= | Silent (SNP) | VAF 44/194 reads (23%) | catalogued as COSV57349609, COSV57386910; called by muse, mutect2, varscan2
- CAMKK2 | c.220C>T p.L74= | Silent (SNP) | VAF 78/267 reads (29%) | catalogued as COSV61215063; called by muse, mutect2, varscan2
- CASP1 | c.720G>A p.R240= (on ENST00000436863 / NM_033292.4; = p.R219= on NM_001223.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 11/45 reads (24%) | catalogued as rs1421114020, COSV100782739; called by muse, mutect2, varscan2
- CBLB | c.2715C>T p.P905= | Silent (SNP) | VAF 6/33 reads (18%) | catalogued as rs758601887, COSV99912937; called by muse, mutect2, varscan2
- CBLN4 | c.573C>T p.S191= | Silent (SNP) | VAF 18/62 reads (29%) | catalogued as COSV50353094; called by muse, mutect2, varscan2
- CCDC197 | c.180C>T p.I60= | Silent (SNP) | VAF 13/60 reads (22%) | called by muse, mutect2
- CCDC83 | c.637C>T p.L213= | Silent (SNP) | VAF 15/51 reads (29%) | catalogued as COSV54702173; called by muse, mutect2, varscan2
- CCM2 | c.429C>T p.S143= | Silent (SNP) | VAF 9/43 reads (21%) | catalogued as COSV51848712; called by muse, mutect2, varscan2
- CCR1 | c.801C>T p.F267= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as rs372934112; called by muse, mutect2, varscan2
- CCT8L2 | c.138C>T p.V46= | Silent (SNP) | VAF 22/96 reads (23%) | catalogued as COSV63462640; called by muse, mutect2, varscan2
- CD163L1 | c.516C>T p.F172= | Silent (SNP) | VAF 19/56 reads (34%) | catalogued as rs759566459, COSV58017345; called by muse, mutect2, varscan2
- CD2 | c.588C>T p.S196= | Silent (SNP) | VAF 8/33 reads (24%) | catalogued as COSV65644331; called by muse, mutect2, varscan2
- CD22 | c.570G>A p.S190= | Silent (SNP) | VAF 27/99 reads (27%) | catalogued as rs761690391, COSV50054291; called by muse, mutect2, varscan2
- CD244 | c.702C>T p.I234= (on ENST00000368033 / NM_001166663.2; = p.I229= on NM_016382.4) | Silent (SNP) | VAF 14/79 reads (18%) | catalogued as rs763753244, COSV100458851, COSV59238640; called by muse, mutect2, varscan2
- CD2BP2 | c.642C>T p.N214= | Silent (SNP) | VAF 20/71 reads (28%) | catalogued as rs376780712; called by muse, mutect2, varscan2
335 further variants in this file (0 protein-altering or splice-affecting, 299 silent, 36 other) are not listed here.
